Somatic mutation profile of tumor specimen C3L-05527-01 (aliquot CPT0286650006) from CPTAC case C3L-05527, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIC; Age at diagnosis: 68.2 years (24,893 days).
Specimen C3L-05527-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Shoulder; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4fab6f92-f4a6-4fd3-9b1c-ed1c4a8b0658.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-05527-31 (Blood Derived Normal), aliquot CPT0286080002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/33d90489-e0f1-4bde-9cd1-20e44d03dbae

The open-access MAF lists 813 somatic variants for this specimen: 504 protein-altering or splice-affecting, 273 silent, 36 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 465, Silent 273, Nonsense Mutation 32, Intron 24, 3'UTR 5, Splice Region 4, 5'UTR 3, 3'Flank 2, Translation Start Site 1, Splice Site 1, In Frame Del 1, RNA 1.

Variants (750 of 813; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AASDHPPT | c.742C>T p.P248S | Missense Mutation (SNP) | VAF 19/322 reads (6%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as rs1391501935; called by muse, mutect2
- ACOD1 | c.1258G>A p.E420K | Missense Mutation (SNP) | VAF 30/429 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV66291285; called by muse, mutect2
- ACOT8 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 26/432 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV54171102; called by muse, mutect2
- ACTRT1 | c.255G>A p.M85I | Missense Mutation (SNP) | VAF 32/635 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.037); catalogued as rs1319324968, COSV64419607; called by muse, mutect2
- ADAMTS10 | c.1460C>T p.S487L | Missense Mutation (SNP) | VAF 20/323 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54353820; called by muse, mutect2
- ADAMTS4 | c.432G>A p.W144* | Nonsense Mutation (SNP) | VAF 28/582 reads (5%) | catalogued as COSV63488194; called by muse, mutect2
- ADCY5 | c.3139G>A p.D1047N | Missense Mutation (SNP) | VAF 33/574 reads (6%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.621); catalogued as COSV59204123; called by muse, mutect2
- ANKS1A | c.2342C>T p.S781F | Missense Mutation (SNP) | VAF 28/568 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV64462378; called by muse, mutect2
- ATP8B3 | c.3824G>A p.G1275E | Missense Mutation (SNP) | VAF 17/482 reads (4%) | SIFT tolerated (0.45); PolyPhen benign (0.007); catalogued as COSV100034602; called by muse, mutect2
- ATP8B4 | c.1874G>A p.R625K | Missense Mutation (SNP) | VAF 20/573 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.434); catalogued as COSV52721492; called by muse, mutect2
- ATP9B | c.877C>T p.L293F | Missense Mutation (SNP) | VAF 24/379 reads (6%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.995); catalogued as COSV56953712; called by muse, mutect2
- ATRN | c.2101C>T p.H701Y | Missense Mutation (SNP) | VAF 22/288 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs1366527803, COSV99496838; called by muse, mutect2
- ATRNL1 | c.620C>T p.S207L | Missense Mutation (SNP) | VAF 9/216 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.468); catalogued as rs368755603, COSV100746539; called by muse, mutect2
- ATRX | c.3086C>T p.P1029L | Missense Mutation (SNP) | VAF 20/476 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.036); catalogued as rs781989664, COSV64877989; called by muse, mutect2
- B3GLCT | c.764C>T p.S255F | Missense Mutation (SNP) | VAF 20/385 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.169); catalogued as COSV100587284, COSV58453460; called by muse, mutect2
- BCL11A | c.1943C>T p.S648L (on ENST00000335712 / NM_001365609.1; = p.S682L on NM_018014.4) | Missense Mutation (SNP) | VAF 33/599 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV59636516; called by muse, mutect2
- BDKRB2 | c.598G>A p.E200K | Missense Mutation (SNP) | VAF 30/574 reads (5%) | SIFT tolerated (0.25); PolyPhen benign (0.21); catalogued as COSV100021613, COSV60013458; called by muse, mutect2
- BHLHA9 | c.647C>T p.P216L | Missense Mutation (SNP) | VAF 35/656 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV66953827; called by muse, mutect2
- BIN1 | c.193C>A p.L65I | Missense Mutation (SNP) | VAF 26/480 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.091); catalogued as COSV52118542; called by muse, mutect2
- BRWD3 | c.3976C>T p.R1326* | Nonsense Mutation (SNP) | VAF 18/428 reads (4%) | catalogued as rs866592729, COSV64746272; called by muse, mutect2
- BTK | c.302C>T p.P101L | Missense Mutation (SNP) | VAF 22/350 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); catalogued as COSV58123854; called by muse, mutect2
- BX276092.9 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.56); catalogued as rs1044848141; called by muse, mutect2
- C16orf90 | c.509G>A p.G170E (on ENST00000399645 / NM_001353385.2; = p.G161E on NM_001080524.2) | Missense Mutation (SNP) | VAF 27/603 reads (4%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.027); catalogued as COSV101290966; called by muse, mutect2
- C1orf226 | c.734G>A p.W245* | Nonsense Mutation (SNP) | VAF 48/676 reads (7%) | catalogued as COSV63394710; called by muse, mutect2
- C1orf94 | c.493C>T p.P165S | Missense Mutation (SNP) | VAF 22/600 reads (4%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.007); catalogued as COSV64915462; called by muse, mutect2
- C6orf132 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 29/711 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.383); catalogued as rs1222387885; called by muse, mutect2
- CALCR | c.134G>A p.R45Q | Missense Mutation (SNP) | VAF 51/576 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.112); catalogued as rs773160307, COSV64006673; called by muse, mutect2
- CAPN11 | c.1283G>A p.G428E | Missense Mutation (SNP) | VAF 22/614 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67238307, COSV67239933; called by muse, mutect2
- CAPSL | c.208G>A p.D70N | Missense Mutation (SNP) | VAF 18/540 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.314); catalogued as COSV101274331, COSV68438029; called by muse, mutect2
- CCDC17 | c.602G>A p.R201Q | Missense Mutation (SNP) | VAF 22/556 reads (4%) | SIFT tolerated (0.15); PolyPhen benign (0.11); catalogued as rs1048761273, COSV51969501, COSV99322283; called by muse, mutect2
- CCDC183 | c.206C>T p.T69I | Missense Mutation (SNP) | VAF 43/516 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as COSV62012405; called by muse, mutect2
- CCDC60 | c.223G>A p.E75K | Missense Mutation (SNP) | VAF 19/485 reads (4%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.737); catalogued as COSV59543363; called by muse, mutect2
- CCSER1 | c.1661C>T p.P554L | Missense Mutation (SNP) | VAF 20/434 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV61480760; called by muse, mutect2
- CD200R1 | c.245C>T p.P82L (on ENST00000471858 / NM_170780.3; = p.P105L on NM_138806.4) | Missense Mutation (SNP) | VAF 25/568 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); catalogued as COSV55599988; called by muse, mutect2
- CENPE | c.1670C>T p.S557L | Missense Mutation (SNP) | VAF 14/261 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs1287350091, COSV54392180; called by muse, mutect2
- CFAP43 | c.1775C>T p.S592F | Missense Mutation (SNP) | VAF 35/588 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1200166388; called by muse, mutect2
- CHD5 | c.2428C>T p.R810C | Missense Mutation (SNP) | VAF 29/337 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1424567700, COSV52411841; called by muse, mutect2
- CIAO3 | c.926C>T p.T309I | Missense Mutation (SNP) | VAF 22/662 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV52403283; called by muse, mutect2
- CLCN6 | c.1985C>T p.S662F | Missense Mutation (SNP) | VAF 32/372 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.202); catalogued as rs772245001; called by muse, mutect2
- CLDN14 | c.404C>T p.A135V | Missense Mutation (SNP) | VAF 26/620 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.338); catalogued as COSV59774092; called by muse, mutect2
- CLDN23 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 26/549 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1317553358, COSV67731733; called by muse, mutect2
- CLK3 | c.392G>A p.R131K | Missense Mutation (SNP) | VAF 24/670 reads (4%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.001); catalogued as rs1166587974, COSV61414220; called by muse, mutect2
- COL15A1 | c.871G>A p.E291K | Missense Mutation (SNP) | VAF 36/582 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.777); catalogued as COSV66647944; called by muse, mutect2
- COL15A1 | c.2191C>T p.P731S | Missense Mutation (SNP) | VAF 22/602 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.793); catalogued as COSV100897806; called by muse, mutect2
- COL21A1 | c.1643G>A p.G548D | Missense Mutation (SNP) | VAF 16/325 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); catalogued as COSV55165792; called by muse, mutect2
- COL4A2 | c.2849G>A p.G950E | Missense Mutation (SNP) | VAF 34/567 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64628883; called by muse, mutect2
- COL4A5 | c.1696C>T p.P566S | Missense Mutation (SNP) | VAF 25/628 reads (4%) | SIFT tolerated (0.06); PolyPhen benign (0.229); catalogued as COSV100088372; called by muse, mutect2
- COL5A1 | c.4720C>T p.Q1574* | Nonsense Mutation (SNP) | VAF 30/529 reads (6%) | catalogued as CM128983; called by muse, mutect2
- CR1 | c.1051C>T p.P351S (on ENST00000367051; = p.P801S on NM_000651.6) | Missense Mutation (SNP) | VAF 21/551 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100887473; called by muse, mutect2
- CREBRF | c.517C>T p.P173S | Missense Mutation (SNP) | VAF 25/458 reads (5%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.538); catalogued as COSV51632782; called by muse, mutect2
- CSMD2 | c.1111G>A p.E371K | Missense Mutation (SNP) | VAF 34/472 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.887); catalogued as rs1026441195, COSV53880885; called by muse, mutect2
- CSMD3 | c.8423C>T p.S2808F (on ENST00000297405 / NM_001363185.1; = p.S2639F on NM_052900.3) | Missense Mutation (SNP) | VAF 14/356 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.073); catalogued as COSV99846243; called by muse, mutect2
- CTAGE4 | c.2165C>T p.P722L | Missense Mutation (SNP) | VAF 80/1318 reads (6%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.844); catalogued as rs778988872; called by muse, mutect2
- CTTNBP2NL | c.1600C>T p.R534* | Nonsense Mutation (SNP) | VAF 28/556 reads (5%) | catalogued as rs1440473775, COSV54745867; called by muse, mutect2
- CYYR1 | c.415C>T p.P139S | Missense Mutation (SNP) | VAF 33/624 reads (5%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV54830425; called by muse, mutect2
- DACT3 | c.1498C>T p.P500S | Missense Mutation (SNP) | VAF 35/828 reads (4%) | SIFT tolerated (0.51); PolyPhen benign (0.057); catalogued as rs1398348764; called by muse, mutect2
- DEFB112 | c.115G>A p.G39R | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.639); catalogued as rs867836847, COSV59182532; called by muse, mutect2
- DENND2C | c.1909G>A p.G637R (on ENST00000393274 / NM_001256404.2; = p.G580R on NM_198459.4) | Missense Mutation (SNP) | VAF 20/506 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs878941975; called by muse, mutect2
- DENND3 | c.1832C>T p.A611V | Missense Mutation (SNP) | VAF 32/604 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV52806830; called by muse, mutect2
- DHX16 | c.2123C>T p.S708L | Missense Mutation (SNP) | VAF 36/600 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1279788475; called by muse, mutect2
- DIO2 | c.797G>A p.Sec266* | Nonsense Mutation (SNP) | VAF 25/408 reads (6%) | catalogued as COSV70444795; called by muse, mutect2
- DKK2 | c.448C>T p.R150* | Nonsense Mutation (SNP) | VAF 27/542 reads (5%) | catalogued as rs1254069801, COSV53397188, COSV53400080; called by muse, mutect2
- DLG1 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 32/334 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.957); catalogued as rs1452989685, COSV58388379, COSV58391297; called by muse, mutect2
- DMRT2 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 35/715 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.534); catalogued as COSV52401021; called by muse, mutect2
- DNAH11 | c.5053G>A p.E1685K | Missense Mutation (SNP) | VAF 22/521 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.64); catalogued as COSV60947438; called by muse, mutect2
- DNM3 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 20/483 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1430116420, COSV62456968; called by muse, mutect2
- DNM3 | c.2269C>T p.P757S (on ENST00000355305 / NM_001350206.2; = p.P751S on NM_015569.5) | Missense Mutation (SNP) | VAF 23/399 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as COSV62454250; called by muse, mutect2
- DPEP1 | c.5G>A p.W2* | Nonsense Mutation (SNP) | VAF 22/412 reads (5%) | catalogued as COSV55362469; called by muse, mutect2
- DPEP3 | c.1156C>T p.R386C | Missense Mutation (SNP) | VAF 33/535 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.552); catalogued as rs895702349; called by muse, mutect2
- DPYSL3 | c.1020G>T p.Q340H | Missense Mutation (SNP) | VAF 23/607 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.895); catalogued as COSV58323550; called by muse, mutect2
- DSCAML1 | c.1676G>A p.R559Q (on ENST00000321322; = p.R499Q on NM_020693.4) | Missense Mutation (SNP) | VAF 16/326 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1484664737, COSV58396830; called by muse, mutect2
- DSG1 | c.2799G>A p.M933I | Missense Mutation (SNP) | VAF 17/524 reads (3%) | SIFT tolerated (0.1); PolyPhen benign (0.003); catalogued as COSV57139718; called by muse, mutect2
- DYNC2H1 | c.3265G>A p.E1089K | Missense Mutation (SNP) | VAF 13/299 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.17); catalogued as COSV62108220; called by muse, mutect2
- ELFN2 | c.841C>T p.L281F | Missense Mutation (SNP) | VAF 39/721 reads (5%) | SIFT tolerated (0.59); PolyPhen possibly damaging (0.759); catalogued as COSV68743839; called by muse, mutect2
- ELOA2 | c.1498G>A p.E500K | Missense Mutation (SNP) | VAF 29/620 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.868); catalogued as COSV55299125; called by muse, mutect2
- EML6 | c.1379C>T p.S460F | Missense Mutation (SNP) | VAF 30/496 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as rs1216367095; called by muse, mutect2
- ERFL | c.1004G>A p.G335D | Missense Mutation (SNP) | VAF 24/592 reads (4%) | SIFT deleterious, low confidence (0); catalogued as rs1200207349; called by muse, mutect2
- FAM135B | c.2971C>T p.H991Y | Missense Mutation (SNP) | VAF 26/540 reads (5%) | SIFT tolerated (0.16); PolyPhen benign (0.133); catalogued as rs867855435, COSV52713217; called by muse, mutect2
- FAM151A | c.1741C>T p.H581Y | Missense Mutation (SNP) | VAF 22/434 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.026); catalogued as rs1047501126; called by muse, mutect2
- FAM78B | c.337C>A p.P113T | Missense Mutation (SNP) | VAF 30/574 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100597723; called by muse, mutect2
- FAM83A | c.1040G>A p.R347Q | Missense Mutation (SNP) | VAF 28/728 reads (4%) | SIFT tolerated (0.99); PolyPhen benign (0.001); catalogued as COSV52684333; called by muse, mutect2
- FBRS | c.814C>T p.P272S (on ENST00000287468; = p.P792S on NM_001105079.3) | Missense Mutation (SNP) | VAF 18/354 reads (5%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.549); catalogued as rs1279937708; called by muse, mutect2
- FHAD1 | c.2439G>A p.M813I | Missense Mutation (SNP) | VAF 31/488 reads (6%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as rs1280484565; called by muse, mutect2
- FNDC1 | c.5522G>A p.G1841E | Missense Mutation (SNP) | VAF 16/355 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51944748; called by muse, mutect2
- FSTL5 | c.502C>T p.P168S | Missense Mutation (SNP) | VAF 16/381 reads (4%) | SIFT tolerated (0.78); PolyPhen benign (0); catalogued as COSV60193580; called by muse, mutect2
- FUT6 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 37/807 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV99744643; called by muse, mutect2
- GAL3ST1 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 34/638 reads (5%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.99); catalogued as rs908336354, COSV58892699; called by muse, mutect2
- GALNTL6 | c.941G>A p.G314E | Missense Mutation (SNP) | VAF 20/370 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV72491829; called by muse, mutect2
- GMNC | c.926C>T p.S309F | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1353542441; called by muse, mutect2
- HDAC4 | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 29/522 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100614118; called by muse, mutect2
- HOXA7 | c.313G>A p.D105N | Missense Mutation (SNP) | VAF 31/632 reads (5%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs1222044457; called by muse, mutect2
- HROB | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 31/549 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.037); catalogued as rs1361151135; called by muse, mutect2
- HSPG2 | c.7432C>T p.P2478S | Missense Mutation (SNP) | VAF 29/428 reads (7%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as COSV65969214; called by muse, mutect2
- IKZF2 | c.1078C>T p.H360Y | Missense Mutation (SNP) | VAF 20/448 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.486); catalogued as rs867126895, COSV59575974; called by muse, mutect2
- IKZF3 | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 20/547 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99499766; called by muse, mutect2
- IL1RAP | c.1994C>T p.P665L | Missense Mutation (SNP) | VAF 38/633 reads (6%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.098); catalogued as COSV58520009; called by muse, mutect2
- ISL2 | c.1067C>T p.P356L | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); catalogued as COSV51957747, COSV51958383; called by muse, mutect2
- ITGA10 | c.1558G>A p.G520R | Missense Mutation (SNP) | VAF 20/560 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100994698; called by muse, mutect2
- JMJD4 | c.107G>A p.R36K | Missense Mutation (SNP) | VAF 19/596 reads (3%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1013732250; called by muse, mutect2
- KCNJ3 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 24/596 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV54540717; called by muse, mutect2
- KCNS3 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 29/601 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868657815, COSV58408348; called by muse, mutect2
- KIF4B | c.2029G>A p.E677K | Missense Mutation (SNP) | VAF 21/549 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.012); catalogued as rs868202509; called by muse, mutect2
- KIF5C | c.1045G>A p.E349K | Missense Mutation (SNP) | VAF 27/563 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.925); catalogued as COSV101276086; called by muse, mutect2
- KRTAP6-2 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 23/485 reads (5%) | PolyPhen benign (0.003); catalogued as rs1204080140, COSV58182617; called by muse, mutect2
- LIMK1 | c.1411-1G>A p.X471_splice | Splice Site (SNP) | VAF 20/308 reads (6%) | catalogued as rs1166424209; called by muse, mutect2
- LMBR1 | c.347C>T p.S116F | Missense Mutation (SNP) | VAF 23/245 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV62223310; called by muse, mutect2, varscan2
- LRP2 | c.244C>T p.P82S | Missense Mutation (SNP) | VAF 22/470 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.124); catalogued as COSV55567333; called by muse, mutect2
- LRRC49 | c.1063_1065del p.R355del | In Frame Del (DEL) | VAF 24/248 reads (10%) | catalogued as rs1275377468; called by mutect2, pindel
- LTBP4 | c.2944C>T p.P982S (on ENST00000308370 / NM_001042544.1; = p.P945S on NM_003573.2) | Missense Mutation (SNP) | VAF 25/576 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs1460228021; called by muse, mutect2
- MACF1 | c.13153G>A p.E4385K (on ENST00000372915; = p.E2318K on NM_012090.5) | Missense Mutation (SNP) | VAF 18/294 reads (6%) | catalogued as COSV57105793; called by muse, mutect2
- MAGEA1 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 21/640 reads (3%) | catalogued as COSV100756698; called by muse, mutect2
- MAGEE2 | c.1304G>A p.G435E | Missense Mutation (SNP) | VAF 30/625 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.374); catalogued as rs1405659827; called by muse, mutect2
- MERTK | c.999G>A p.M333I | Missense Mutation (SNP) | VAF 22/498 reads (4%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV54931674; called by muse, mutect2
- MRGPRD | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 31/638 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.042); catalogued as COSV58423134; called by muse, mutect2
- MTUS2 | c.1420C>T p.P474S | Missense Mutation (SNP) | VAF 25/579 reads (4%) | SIFT tolerated (0.48); PolyPhen benign (0.011); catalogued as rs1333902587; called by muse, mutect2
- MUC16 | c.6578C>T p.S2193F | Missense Mutation (SNP) | VAF 28/426 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV67462513; called by muse, mutect2
- MUC17 | c.5882C>T p.S1961F | Missense Mutation (SNP) | VAF 25/673 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.006); catalogued as COSV60287818; called by muse, mutect2
- MXRA5 | c.6464G>A p.R2155K | Missense Mutation (SNP) | VAF 44/727 reads (6%) | SIFT tolerated (0.18); PolyPhen benign (0.096); catalogued as COSV54222731; called by muse, mutect2
- NCKIPSD | c.1034C>T p.S345L | Missense Mutation (SNP) | VAF 40/564 reads (7%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as rs1465244567; called by muse, mutect2
- NCR1 | c.380C>T p.S127L | Missense Mutation (SNP) | VAF 25/636 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.1); catalogued as rs142626797; called by muse, mutect2
- NDUFS8 | c.319G>A p.G107R | Missense Mutation (SNP) | VAF 27/672 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs1400523462; called by muse, mutect2
- NOVA1 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 27/602 reads (4%) | catalogued as COSV57472701, COSV57490260; called by muse, mutect2
- NRF1 | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 32/328 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); catalogued as COSV56214648; called by muse, mutect2, varscan2
- OBP2A | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 30/428 reads (7%) | SIFT tolerated (0.13); PolyPhen benign (0.137); catalogued as rs372804273; called by muse, mutect2
- OIT3 | c.170G>A p.G57E | Missense Mutation (SNP) | VAF 19/650 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1381915266; called by muse, mutect2
- OLFML1 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 24/566 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1477099269, COSV100206754; called by muse, mutect2
- OR51G2 | c.743C>T p.S248F | Missense Mutation (SNP) | VAF 24/568 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs867001321, COSV58992760; called by muse, mutect2
- OR8J1 | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 22/646 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.216); catalogued as COSV57318251; called by muse, mutect2
- PAPPA | c.1646C>T p.S549F | Missense Mutation (SNP) | VAF 24/400 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1311925603, COSV60282855; called by muse, mutect2
- PASD1 | c.262G>A p.E88K | Missense Mutation (SNP) | VAF 16/400 reads (4%) | SIFT tolerated (0.16); PolyPhen benign (0.021); catalogued as COSV100949649; called by muse, mutect2
- PCDHA12 | c.2351T>C p.L784S | Missense Mutation (SNP) | VAF 30/380 reads (8%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.001); catalogued as COSV56551468; called by muse, mutect2
- PCDHB4 | c.683G>A p.R228Q | Missense Mutation (SNP) | VAF 26/623 reads (4%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.025); catalogued as COSV52019932; called by muse, mutect2
- PGGHG | c.2168C>T p.S723F | Missense Mutation (SNP) | VAF 44/642 reads (7%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); catalogued as COSV66887693; called by muse, mutect2
- PIK3CA | c.2720C>G p.A907G | Missense Mutation (SNP) | VAF 30/459 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV56024907; called by muse, mutect2
- PIP | c.286A>T p.K96* | Nonsense Mutation (SNP) | VAF 42/558 reads (8%) | catalogued as COSV52120376; called by muse, mutect2
- PKHD1L1 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 23/464 reads (5%) | SIFT tolerated (0.21); PolyPhen benign (0.031); catalogued as COSV65737606; called by muse, mutect2
- PKM | c.1259C>T p.S420F | Missense Mutation (SNP) | VAF 31/563 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1436364737; called by muse, mutect2
- PLA2G4D | c.2323G>A p.E775K | Missense Mutation (SNP) | VAF 24/598 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.084); catalogued as COSV51820833; called by muse, mutect2
- PNLIPRP1 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 13/322 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.234); catalogued as COSV62611439; called by muse, mutect2
- POLR2B | c.805A>G p.I269V | Missense Mutation (SNP) | VAF 24/393 reads (6%) | SIFT tolerated (0.49); PolyPhen benign (0.014); catalogued as rs1340224854; called by muse, mutect2
- POLRMT | c.1339C>T p.R447W | Missense Mutation (SNP) | VAF 30/634 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as rs949994185; called by muse, mutect2
- PRAMEF2 | c.949C>T p.P317S | Missense Mutation (SNP) | VAF 31/563 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.548); catalogued as COSV53576226; called by muse, mutect2
- PRDM9 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 23/364 reads (6%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.014); catalogued as COSV57006651, COSV57009635; called by muse, mutect2
- PRKCG | c.1996G>A p.D666N | Missense Mutation (SNP) | VAF 50/668 reads (7%) | SIFT tolerated (0.45); PolyPhen benign (0.199); catalogued as rs373369366; called by muse, mutect2
- PRRG3 | c.47G>A p.R16Q | Missense Mutation (SNP) | VAF 40/754 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.704); catalogued as COSV64850928; called by muse, mutect2
- RBBP8NL | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 48/844 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1437063562, COSV99079160; called by muse, mutect2
- RELN | c.6214G>A p.E2072K | Missense Mutation (SNP) | VAF 39/561 reads (7%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.941); catalogued as rs147042966; called by muse, mutect2
- RIC3 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 30/630 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.731); catalogued as rs1299855450; called by muse, mutect2
- RLN3 | c.394G>A p.G132R | Missense Mutation (SNP) | VAF 21/667 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99652358; called by muse, mutect2
- SATB2 | c.1781C>T p.S594F | Missense Mutation (SNP) | VAF 23/408 reads (6%) | SIFT tolerated (0.23); PolyPhen benign (0.36); catalogued as COSV53488848, COSV53489861; called by muse, mutect2
- SBF1 | c.212C>T p.T71I | Missense Mutation (SNP) | VAF 30/464 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1171644927, COSV62370317; called by muse, mutect2
- SCAF1 | c.2888C>T p.S963F | Missense Mutation (SNP) | VAF 25/666 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs1434563618; called by muse, mutect2
- SCN1A | c.2361G>A p.M787I (on ENST00000303395 / NM_001202435.3; = p.M776I on NM_006920.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/410 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.082); catalogued as COSV57660739, COSV57680767; called by muse, mutect2
- SCN9A | c.3163G>A p.E1055K (on ENST00000303354; = p.E1044K on NM_002977.3) | Missense Mutation (SNP) | VAF 21/550 reads (4%) | SIFT tolerated (0.3); PolyPhen benign (0.01); catalogued as COSV57619461; called by muse, mutect2
- SELP | c.263C>T p.S88F | Missense Mutation (SNP) | VAF 24/542 reads (4%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.655); catalogued as rs1293111304, COSV99741376; called by muse, mutect2
- SEMA4F | c.280G>A p.G94R | Missense Mutation (SNP) | VAF 24/448 reads (5%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV100335876; called by muse, mutect2
- SIDT2 | c.716C>T p.P239L | Missense Mutation (SNP) | VAF 16/522 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV99638095; called by muse, mutect2
- SLC26A9 | c.2296G>A p.E766K | Missense Mutation (SNP) | VAF 40/507 reads (8%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.051); catalogued as rs770597929; called by muse, mutect2
- SLC27A4 | c.83C>T p.S28F | Missense Mutation (SNP) | VAF 53/641 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.73); catalogued as rs768263866, COSV55960793; called by muse, mutect2
- SLC38A5 | c.850C>T p.R284W | Missense Mutation (SNP) | VAF 31/454 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.773); catalogued as rs781958231; called by muse, mutect2
- SLC38A5 | c.82C>T p.P28S | Missense Mutation (SNP) | VAF 28/599 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0.01); catalogued as rs1383215872; called by muse, mutect2
- SLC41A3 | c.191C>T p.S64F | Missense Mutation (SNP) | VAF 22/568 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.467); catalogued as rs1352408125; called by muse, mutect2
- SLCO1B3 | c.1351C>T p.H451Y | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.091); catalogued as rs1292889922; called by muse, mutect2
- SORBS1 | c.3209C>T p.A1070V | Missense Mutation (SNP) | VAF 22/548 reads (4%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0); catalogued as rs1346791741; called by muse, mutect2
- SPANXN3 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 32/804 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen probably damaging (0.991); catalogued as COSV65140561; called by muse, mutect2
- SPOCK3 | c.1097G>A p.G366E | Missense Mutation (SNP) | VAF 22/504 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62730151; called by muse, mutect2
- SRARP | c.155G>A p.G52E | Missense Mutation (SNP) | VAF 40/682 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs1305958821; called by muse, mutect2
- ST6GAL2 | c.482G>A p.G161E | Missense Mutation (SNP) | VAF 38/732 reads (5%) | PolyPhen benign (0.014); catalogued as COSV64528315; called by muse, mutect2
- STOX2 | c.2648C>T p.P883L | Missense Mutation (SNP) | VAF 22/527 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.056); catalogued as COSV100408606; called by muse, mutect2
- SULT1C3 | c.427G>A p.D143N | Missense Mutation (SNP) | VAF 18/275 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61254193; called by muse, mutect2
- SYNDIG1L | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 26/594 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1275628219, COSV100526402, COSV59046911; called by muse, mutect2
- SYNE1 | c.4841C>T p.A1614V (on ENST00000367255 / NM_182961.4; = p.A1621V on NM_033071.3) | Missense Mutation (SNP) | VAF 24/474 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.01); catalogued as COSV55034512; called by muse, mutect2
- SYT1 | c.1012C>T p.P338S | Missense Mutation (SNP) | VAF 18/405 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54041684; called by muse, mutect2
- TBCD | c.2752C>T p.R918C | Missense Mutation (SNP) | VAF 32/644 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1422765982, COSV62803858; called by muse, mutect2
- TCERG1L | c.364C>T p.P122S | Missense Mutation (SNP) | VAF 18/370 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV64052580; called by muse, mutect2
- THSD7B | c.208C>T p.H70Y | Missense Mutation (SNP) | VAF 21/464 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs865835196, COSV55672257; called by muse, mutect2
- TLR3 | c.137C>T p.P46L | Missense Mutation (SNP) | VAF 30/530 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV99710915; called by muse, mutect2
- TMPRSS15 | c.1810G>A p.D604N | Missense Mutation (SNP) | VAF 22/469 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV53040130; called by muse, mutect2
- TNXB | c.7532G>A p.G2511D (on ENST00000647633; = p.G2264D on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/556 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV64473033; called by muse, mutect2
- TRPM2 | c.658G>A p.E220K | Missense Mutation (SNP) | VAF 38/658 reads (6%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV55968418; called by muse, mutect2
- TUBA3E | c.478G>A p.D160N | Missense Mutation (SNP) | VAF 28/515 reads (5%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.048); catalogued as rs1396956414; called by muse, mutect2
- UBN2 | c.3808C>T p.P1270S | Missense Mutation (SNP) | VAF 32/513 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV56027458; called by muse, mutect2
- UGT3A2 | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 36/547 reads (7%) | SIFT tolerated (0.06); PolyPhen benign (0.186); catalogued as COSV56929765; called by muse, mutect2
- UNC13C | c.859G>A p.E287K | Missense Mutation (SNP) | VAF 16/488 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV52860266; called by muse, mutect2
- USP20 | c.1768C>T p.R590W | Missense Mutation (SNP) | VAF 30/438 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs1275156148, COSV59612640; called by muse, mutect2
- USP20 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 15/460 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as rs1290367725; called by muse, mutect2
- WDFY4 | c.844C>T p.P282S | Missense Mutation (SNP) | VAF 22/570 reads (4%) | SIFT tolerated (0.58); PolyPhen benign (0.014); catalogued as rs1565135078; called by muse, mutect2
- WDR87 | c.8444C>T p.P2815L | Missense Mutation (SNP) | VAF 23/521 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.144); catalogued as rs1040746672, COSV58208560; called by muse, mutect2
- WNT2 | c.565C>T p.H189Y | Missense Mutation (SNP) | VAF 34/425 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs753346526; called by muse, mutect2
- WNT3A | c.238C>T p.Q80* | Nonsense Mutation (SNP) | VAF 20/649 reads (3%) | catalogued as COSV52729560; called by muse, mutect2
- XKR7 | c.1469G>A p.G490E | Missense Mutation (SNP) | VAF 33/736 reads (4%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.999); catalogued as rs1482664633, COSV73813424; called by muse, mutect2
- YIPF7 | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 20/470 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); catalogued as COSV60656343; called by muse, mutect2
- ZC3H12D | c.767C>T p.S256F | Missense Mutation (SNP) | VAF 34/500 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.896); catalogued as rs1350077187; called by muse, mutect2
- ZFR2 | c.381G>A p.G127= | Splice Region (SNP) | VAF 36/464 reads (8%) | catalogued as rs1465190874; called by muse, mutect2
- ZNF521 | c.2824G>A p.E942K | Missense Mutation (SNP) | VAF 48/548 reads (9%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs751157753, COSV64124837; called by muse, mutect2
- ZNF646 | c.80G>A p.R27Q | Missense Mutation (SNP) | VAF 22/650 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.117); catalogued as rs1275237333, COSV56212235; called by muse, mutect2
- ZNF823 | c.379G>A p.E127K (on ENST00000341191 / NM_001297610.2; = p.E83K on NM_017507.2) | Missense Mutation (SNP) | VAF 26/518 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.285); catalogued as rs1568466172; called by muse, mutect2
- ZNF831 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 34/680 reads (5%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as rs1238685026; called by muse, mutect2
- ZNF85 | c.922C>T p.H308Y | Missense Mutation (SNP) | VAF 22/535 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV60213050; called by muse, mutect2
- ABCB11 | c.1379G>A p.G460E | Missense Mutation (SNP) | VAF 12/356 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ACADL | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 22/502 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.451); called by muse, mutect2
- ACE2 | c.992C>T p.S331F | Missense Mutation (SNP) | VAF 24/572 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ACTR6 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 19/465 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ADARB2 | c.1917G>A p.M639I | Missense Mutation (SNP) | VAF 29/664 reads (4%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2
- ADCY4 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 27/431 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.181); called by muse, mutect2
- ADCY5 | c.3029C>T p.S1010F | Missense Mutation (SNP) | VAF 22/512 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.085); called by muse, mutect2
- AFTPH | c.190C>T p.H64Y | Missense Mutation (SNP) | VAF 16/394 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- AL772284.1 | c.751G>A p.E251K | Missense Mutation (SNP) | VAF 36/714 reads (5%) | SIFT tolerated (0.77); called by muse, mutect2
- ALDH1L1 | c.638G>T p.W213L | Missense Mutation (SNP) | VAF 24/432 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.074); called by muse, mutect2
- ALPK3 | c.2116G>A p.G706R | Missense Mutation (SNP) | VAF 33/656 reads (5%) | SIFT tolerated, low confidence (0.09); called by muse, mutect2
- ANKIB1 | c.3028G>A p.G1010S | Missense Mutation (SNP) | VAF 43/507 reads (8%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); called by muse, mutect2
- ANLN | c.1972T>C p.S658P | Missense Mutation (SNP) | VAF 34/512 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- AP1M2 | c.11C>T p.S4L | Missense Mutation (SNP) | VAF 24/650 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- AP3D1 | c.2062T>C p.S688P | Missense Mutation (SNP) | VAF 20/583 reads (3%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.959); called by muse, mutect2
- APMAP | c.775C>T p.P259S | Missense Mutation (SNP) | VAF 40/678 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.943); called by muse, mutect2
- APOB | c.11632C>T p.P3878S | Missense Mutation (SNP) | VAF 23/493 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ARFGEF1 | c.787G>A p.G263R | Missense Mutation (SNP) | VAF 24/600 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2
- ARHGAP6 | c.512G>A p.R171K | Missense Mutation (SNP) | VAF 28/700 reads (4%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.956); called by muse, mutect2
- ARHGEF15 | c.547G>A p.G183R | Missense Mutation (SNP) | VAF 36/500 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.056); called by muse, mutect2
- ARHGEF16 | c.1991G>A p.G664E | Missense Mutation (SNP) | VAF 29/450 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ARHGEF4 | c.1243T>C p.S415P | Missense Mutation (SNP) | VAF 20/402 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0.208); called by muse, mutect2
- ARSB | c.692C>T p.P231L | Missense Mutation (SNP) | VAF 11/302 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ATP2A1 | c.137G>A p.G46E | Missense Mutation (SNP) | VAF 18/399 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.115); called by muse, mutect2
- ATXN2L | c.685C>T p.Q229* | Nonsense Mutation (SNP) | VAF 24/533 reads (5%) | called by muse, mutect2
- BIRC6 | c.11156T>C p.L3719S | Missense Mutation (SNP) | VAF 28/564 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BIVM-ERCC5 | c.4475C>T p.S1492F | Missense Mutation (SNP) | VAF 32/495 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2
- C11orf91 | c.221C>T p.P74L | Missense Mutation (SNP) | VAF 21/314 reads (7%) | SIFT tolerated, low confidence (0.27); PolyPhen possibly damaging (0.856); called by muse, mutect2
- C1orf232 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 34/433 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.203); called by muse, mutect2
- C2orf16 | c.3942G>A p.M1314I | Missense Mutation (SNP) | VAF 19/359 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.351); called by muse, mutect2
- C2orf16 | c.5866A>G p.R1956G | Missense Mutation (SNP) | VAF 16/406 reads (4%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); called by muse, mutect2
- C8orf82 | c.469C>T p.P157S | Missense Mutation (SNP) | VAF 44/830 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.801); called by muse, mutect2
- CACNG6 | c.110G>A p.G37E | Missense Mutation (SNP) | VAF 27/673 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.642); called by muse, mutect2
- CASZ1 | c.2033C>T p.T678I | Missense Mutation (SNP) | VAF 53/565 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); called by muse, mutect2
- CCDC153 | c.623C>T p.P208L | Missense Mutation (SNP) | VAF 18/374 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.006); called by muse, mutect2
- CCDC168 | c.20464G>A p.E6822K | Missense Mutation (SNP) | VAF 21/468 reads (4%) | SIFT tolerated (0.36); PolyPhen benign (0.047); called by muse, mutect2
- CD8B | c.615G>A p.M205I | Missense Mutation (SNP) | VAF 22/464 reads (5%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2
- CDHR2 | c.2464G>A p.G822S | Missense Mutation (SNP) | VAF 28/654 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.46); called by muse, mutect2
- CDKN2D | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 18/372 reads (5%) | SIFT tolerated (0.62); PolyPhen benign (0.02); called by muse, mutect2
- CEP41 | c.218T>C p.V73A | Missense Mutation (SNP) | VAF 18/432 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- CERS1 | c.316T>G p.F106V | Missense Mutation (SNP) | VAF 34/642 reads (5%) | SIFT tolerated (0.09); PolyPhen benign (0.01); called by muse, mutect2
- CFAP100 | c.559G>A p.E187K | Missense Mutation (SNP) | VAF 44/645 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.029); called by muse, mutect2
- CLPTM1 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLSTN1 | c.283C>T p.P95S (on ENST00000377298 / NM_001009566.3; = p.P85S on NM_014944.4) | Missense Mutation (SNP) | VAF 20/488 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- COL16A1 | c.1406C>T p.P469L | Missense Mutation (SNP) | VAF 20/560 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- COL20A1 | c.3119C>T p.A1040V | Missense Mutation (SNP) | VAF 34/578 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- COL2A1 | c.3391G>A p.G1131R | Missense Mutation (SNP) | VAF 32/510 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL4A2 | c.367C>T p.P123S | Missense Mutation (SNP) | VAF 32/478 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- COL5A3 | c.260C>T p.P87L | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- COL6A2 | c.2290C>T p.H764Y | Missense Mutation (SNP) | VAF 27/481 reads (6%) | SIFT tolerated (0.09); PolyPhen benign (0.012); called by muse, mutect2
- COL7A1 | c.7895G>A p.G2632E | Missense Mutation (SNP) | VAF 42/555 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CPXCR1 | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 27/634 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.245); called by muse, mutect2
- CPXM2 | c.123G>A p.W41* | Nonsense Mutation (SNP) | VAF 42/607 reads (7%) | called by muse, mutect2
- CRY2 | c.142C>T p.R48C | Missense Mutation (SNP) | VAF 45/875 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.037); called by muse, mutect2
- CRYBG2 | c.1969C>T p.P657S | Missense Mutation (SNP) | VAF 17/434 reads (4%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.062); called by muse, mutect2
- CST9 | c.190G>A p.E64K | Missense Mutation (SNP) | VAF 27/458 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.542); called by muse, mutect2
- CTNNA2 | c.677C>T p.A226V | Missense Mutation (SNP) | VAF 26/584 reads (4%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.63); called by muse, mutect2
- CYLC1 | c.1816A>T p.K606* | Nonsense Mutation (SNP) | VAF 21/540 reads (4%) | called by muse, mutect2
- CYLC1 | c.1817A>G p.K606R | Missense Mutation (SNP) | VAF 21/537 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.013); called by muse, mutect2
- CYP19A1 | c.628+6G>A | Splice Region (SNP) | VAF 28/630 reads (4%) | called by muse, mutect2
- CYP4F22 | c.423G>A p.G141= | Splice Region (SNP) | VAF 21/432 reads (5%) | called by muse, mutect2
- DACT1 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 26/736 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.025); called by muse, mutect2
- DAGLA | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 20/482 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.564); called by muse, mutect2
- DAO | c.960G>A p.W320* | Nonsense Mutation (SNP) | VAF 14/339 reads (4%) | called by muse, mutect2
- DAPK1 | c.2119C>A p.L707I | Missense Mutation (SNP) | VAF 26/517 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); called by muse, mutect2
- DCLK3 | c.431G>A p.R144K | Missense Mutation (SNP) | VAF 42/579 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, mutect2
- DDB1 | c.431C>T p.P144L | Missense Mutation (SNP) | VAF 17/442 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DDX60 | c.401T>G p.F134C | Missense Mutation (SNP) | VAF 18/474 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.241); called by muse, mutect2
- DGKH | c.3439C>T p.P1147S | Missense Mutation (SNP) | VAF 19/356 reads (5%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2
- DLGAP2 | c.751A>G p.K251E | Missense Mutation (SNP) | VAF 32/856 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2
- DOCK10 | c.6029C>T p.P2010L | Missense Mutation (SNP) | VAF 18/344 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- DOCK6 | c.4157C>T p.T1386I | Missense Mutation (SNP) | VAF 24/444 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.158); called by muse, mutect2
- DPP3 | c.1771C>T p.P591S | Missense Mutation (SNP) | VAF 27/672 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.007); called by muse, mutect2
- DPYS | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 20/472 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.826); called by muse, mutect2
- DSP | c.3976G>A p.E1326K | Missense Mutation (SNP) | VAF 16/482 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2
- DSP | c.4663G>A p.D1555N | Missense Mutation (SNP) | VAF 18/538 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.006); called by muse, mutect2
- ECI1 | c.431C>T p.S144F | Missense Mutation (SNP) | VAF 18/396 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); called by muse, mutect2
- ECPAS | c.4355C>T p.S1452F | Missense Mutation (SNP) | VAF 22/336 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); called by muse, mutect2
- EFCAB8 | c.2737C>T p.P913S | Missense Mutation (SNP) | VAF 28/516 reads (5%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.615); called by muse, mutect2
- ELMO1 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 34/498 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELMO1 | c.2140C>T p.P714S | Missense Mutation (SNP) | VAF 34/500 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ELOA2 | c.959T>C p.L320P | Missense Mutation (SNP) | VAF 28/582 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.063); called by muse, mutect2
- F13A1 | c.1204G>A p.E402K | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FAM111B | c.1124C>T p.A375V | Missense Mutation (SNP) | VAF 21/532 reads (4%) | SIFT tolerated (0.73); PolyPhen benign (0.001); called by muse, mutect2
- FAM163A | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 49/710 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- FAM171B | c.1538G>C p.R513T | Missense Mutation (SNP) | VAF 32/553 reads (6%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.629); called by muse, mutect2
- FAM83G | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 22/496 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); called by muse, mutect2
- FBXO42 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 20/179 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.096); called by muse, mutect2, varscan2
- FER1L5 | c.572C>T p.S191F | Missense Mutation (SNP) | VAF 30/583 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.091); called by muse, mutect2
- FIBIN | c.133G>A p.E45K | Missense Mutation (SNP) | VAF 31/592 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.209); called by muse, mutect2
- FLG | c.11962G>A p.E3988K | Missense Mutation (SNP) | VAF 34/544 reads (6%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2
- FLNA | c.1067T>C p.V356A | Missense Mutation (SNP) | VAF 22/398 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.443); called by muse, mutect2
- FOXJ2 | c.761C>T p.S254F | Missense Mutation (SNP) | VAF 33/488 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- GAB4 | c.159G>T p.K53N | Missense Mutation (SNP) | VAF 28/392 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.012); called by muse, mutect2
- GAS2L2 | c.2162C>T p.P721L | Missense Mutation (SNP) | VAF 30/592 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2
- GCNT3 | c.399T>G p.I133M | Missense Mutation (SNP) | VAF 24/378 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.89); called by muse, mutect2
- GJB4 | c.132G>A p.W44* | Nonsense Mutation (SNP) | VAF 43/610 reads (7%) | called by muse, mutect2
- GLT6D1 | c.72G>A p.R24= | Splice Region (SNP) | VAF 28/477 reads (6%) | called by muse, mutect2
- GMEB1 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 20/329 reads (6%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.483); called by muse, mutect2
- GNB4 | c.280C>T p.P94S | Missense Mutation (SNP) | VAF 28/376 reads (7%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2
- GPR135 | c.128C>T p.S43F | Missense Mutation (SNP) | VAF 46/722 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.879); called by muse, mutect2
- GPR151 | c.85C>T p.P29S | Missense Mutation (SNP) | VAF 24/509 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.074); called by muse, mutect2
- GPR55 | c.463C>T p.P155S | Missense Mutation (SNP) | VAF 22/547 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.508); called by muse, mutect2
- GRM5 | c.2642G>A p.R881K | Missense Mutation (SNP) | VAF 19/428 reads (4%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.815); called by muse, mutect2
- GRXCR2 | c.149C>T p.P50L | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- GTPBP8 | c.523G>A p.D175N | Missense Mutation (SNP) | VAF 24/440 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.857); called by muse, mutect2
- GUCY1B1 | c.443G>A p.G148E | Missense Mutation (SNP) | VAF 24/508 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HAS1 | c.1559G>A p.S520N | Missense Mutation (SNP) | VAF 32/753 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.307); called by muse, mutect2
- HAVCR1 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 20/544 reads (4%) | called by muse, mutect2
- HBM | c.376G>A p.D126N | Missense Mutation (SNP) | VAF 18/508 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- HOXC13 | c.941A>G p.K314R | Missense Mutation (SNP) | VAF 18/446 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- HPX | c.379G>A p.G127R | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); called by muse, mutect2
- HTR5A | c.764C>T p.P255L | Missense Mutation (SNP) | VAF 43/452 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.328); called by muse, mutect2
- IGFBP5 | c.94G>A p.E32K | Missense Mutation (SNP) | VAF 36/662 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.233); called by muse, mutect2
- IGKV2D-24 | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 15/260 reads (6%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.541); called by muse, mutect2
- IGLV8-61 | c.176C>T p.P59L | Missense Mutation (SNP) | VAF 12/340 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); called by muse, mutect2
- IKZF1 | c.1006G>A p.G336S | Missense Mutation (SNP) | VAF 29/636 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.035); called by muse, mutect2
- IKZF1 | c.1007G>A p.G336D | Missense Mutation (SNP) | VAF 29/634 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.58); called by muse, mutect2
- IL1RAPL2 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 10/286 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- ILDR1 | c.702G>A p.M234I | Missense Mutation (SNP) | VAF 26/516 reads (5%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2
- INHA | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 25/374 reads (7%) | PolyPhen probably damaging (0.954); called by muse, mutect2
- ISLR | c.1232G>A p.G411D | Missense Mutation (SNP) | VAF 44/676 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.782); called by muse, mutect2
- ITGB4 | c.2177C>T p.A726V | Missense Mutation (SNP) | VAF 21/452 reads (5%) | SIFT tolerated (0.17); PolyPhen benign (0.007); called by muse, mutect2
- ITGBL1 | c.416G>A p.S139N | Missense Mutation (SNP) | VAF 18/444 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.065); called by muse, mutect2
- ITIH6 | c.1268C>T p.S423F | Missense Mutation (SNP) | VAF 36/670 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.425); called by muse, mutect2
- JAG1 | c.1682C>T p.S561L | Missense Mutation (SNP) | VAF 27/544 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); called by muse, mutect2
- KCNA6 | c.1511C>T p.A504V | Missense Mutation (SNP) | VAF 20/527 reads (4%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); called by muse, mutect2
- KCNH8 | c.800T>A p.L267H | Missense Mutation (SNP) | VAF 22/324 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- KCP | c.2830G>A p.G944R (on ENST00000620378; = p.G1004R on NM_001366122.1) | Missense Mutation (SNP) | VAF 38/518 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); called by muse, mutect2
- KHSRP | c.1835C>T p.P612L | Missense Mutation (SNP) | VAF 44/659 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.875); called by muse, mutect2
- KIAA1671 | c.2466G>A p.W822* | Nonsense Mutation (SNP) | VAF 22/574 reads (4%) | called by muse, mutect2
- KLHL20 | c.77C>T p.T26I | Missense Mutation (SNP) | VAF 17/466 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.026); called by muse, mutect2
- KLHL33 | c.266G>A p.R89K | Missense Mutation (SNP) | VAF 38/664 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0); called by muse, mutect2
- KREMEN2 | c.1102C>T p.R368W | Missense Mutation (SNP) | VAF 44/772 reads (6%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.727); called by muse, mutect2
- KRT27 | c.461C>A p.T154N | Missense Mutation (SNP) | VAF 20/410 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.098); called by muse, mutect2
- KRTAP5-5 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 38/688 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- LAMB2 | c.1274C>T p.S425F | Missense Mutation (SNP) | VAF 25/508 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.319); called by muse, mutect2
- LMTK3 | c.1354C>T p.P452S | Missense Mutation (SNP) | VAF 30/684 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2
- LRG1 | c.445G>A p.E149K | Missense Mutation (SNP) | VAF 28/607 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.055); called by muse, mutect2
- LRP1B | c.1268A>T p.E423V | Missense Mutation (SNP) | VAF 16/294 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- LRP2 | c.245C>T p.P82L | Missense Mutation (SNP) | VAF 22/474 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.791); called by muse, mutect2
- LRRC7 | c.4187C>T p.P1396L (on ENST00000651989 / NM_001370785.2; = p.P1316L on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 22/446 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.627); called by muse, mutect2
- LRRK1 | c.473C>T p.A158V | Missense Mutation (SNP) | VAF 34/622 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0.026); called by muse, mutect2
- LRRN2 | c.2075C>T p.P692L | Missense Mutation (SNP) | VAF 46/532 reads (9%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- LTB | c.448G>A p.G150R | Missense Mutation (SNP) | VAF 38/918 reads (4%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2
- LYNX1 | c.254G>A p.C85Y | Missense Mutation (SNP) | VAF 41/828 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- LYRM2 | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 21/592 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.394); called by muse, mutect2
- MAGEB10 | c.994G>A p.A332T | Missense Mutation (SNP) | VAF 28/548 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.132); called by muse, mutect2
- MAGEC3 | c.1132G>A p.D378N | Missense Mutation (SNP) | VAF 30/789 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.066); called by muse, mutect2
- MAN2B2 | c.2113C>T p.Q705* | Nonsense Mutation (SNP) | VAF 45/694 reads (6%) | called by muse, mutect2
- MAP3K11 | c.1946C>T p.T649I | Missense Mutation (SNP) | VAF 40/824 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.969); called by muse, mutect2
- MAPRE3 | c.296G>A p.G99E | Missense Mutation (SNP) | VAF 16/258 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MBD4 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 53/616 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0); called by muse, mutect2
- MDC1 | c.3689G>A p.G1230E | Missense Mutation (SNP) | VAF 42/916 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.018); called by muse, mutect2
- MEF2B | c.377C>T p.P126L | Missense Mutation (SNP) | VAF 26/528 reads (5%) | SIFT tolerated (0.05); PolyPhen benign (0.115); called by muse, mutect2
- MEOX2 | c.527A>C p.E176A | Missense Mutation (SNP) | VAF 13/312 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.2); called by muse, mutect2
- MERTK | c.2950G>A p.E984K | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.007); called by muse, mutect2
- MFSD3 | c.805G>A p.G269S | Missense Mutation (SNP) | VAF 24/423 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2
- MRGPRG | c.390G>A p.W130* | Nonsense Mutation (SNP) | VAF 36/816 reads (4%) | called by muse, mutect2
- MRGPRG | c.389G>A p.W130* | Nonsense Mutation (SNP) | VAF 34/811 reads (4%) | called by muse, mutect2
- MRPL53 | c.169C>T p.H57Y | Missense Mutation (SNP) | VAF 26/548 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); called by muse, mutect2
- MSANTD2 | c.1555C>T p.P519S (on ENST00000374979 / NM_001308027.2; = p.P467S on NM_024631.4) | Missense Mutation (SNP) | VAF 24/548 reads (4%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.095); called by muse, mutect2
- MUC16 | c.22597C>T p.Q7533* | Nonsense Mutation (SNP) | VAF 21/556 reads (4%) | called by muse, mutect2
- MUC16 | c.18524C>T p.S6175L | Missense Mutation (SNP) | VAF 26/503 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- MUC4 | c.14768C>T p.T4923I (on ENST00000463781 / NM_018406.7; = p.T687I on NM_004532.6) | Missense Mutation (SNP) | VAF 28/885 reads (3%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); called by muse, mutect2
- MUC4 | c.14299G>A p.D4767N (on ENST00000463781 / NM_018406.7; = p.D531N on NM_004532.6) | Missense Mutation (SNP) | VAF 30/723 reads (4%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- MXRA5 | c.5813G>A p.R1938K | Missense Mutation (SNP) | VAF 24/661 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2
- MYH11 | c.3902G>A p.G1301E | Missense Mutation (SNP) | VAF 20/502 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.297); called by muse, mutect2
- MYH14 | c.1456C>T p.Q486* | Nonsense Mutation (SNP) | VAF 19/387 reads (5%) | called by muse, mutect2
- MYH8 | c.3241G>A p.E1081K | Missense Mutation (SNP) | VAF 24/374 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.633); called by muse, mutect2
- MYO15A | c.2273C>T p.P758L | Missense Mutation (SNP) | VAF 25/725 reads (3%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2
- MYO3B | c.104A>T p.K35I | Missense Mutation (SNP) | VAF 18/483 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NACAD | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 40/976 reads (4%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.65); called by muse, mutect2
- NACAD | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 41/976 reads (4%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2
- NAPB | c.830C>T p.T277I | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2
- NEB | c.1853C>T p.P618L | Missense Mutation (SNP) | VAF 20/425 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- NEB | c.686G>A p.R229K | Missense Mutation (SNP) | VAF 21/511 reads (4%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.977); called by muse, mutect2
- NLRP7 | c.1310G>T p.R437M | Missense Mutation (SNP) | VAF 40/890 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.398); called by muse, mutect2
- NMI | c.786G>A p.M262I | Missense Mutation (SNP) | VAF 16/372 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2
- NPIPB7 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 50/583 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- NTSR2 | c.778G>A p.E260K | Missense Mutation (SNP) | VAF 31/645 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.476); called by muse, mutect2
- NUP214 | c.2975A>T p.Q992L | Missense Mutation (SNP) | VAF 33/626 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); called by muse, mutect2
- NXN | c.646G>A p.V216M | Missense Mutation (SNP) | VAF 26/532 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2
- NXN | c.546T>G p.N182K | Missense Mutation (SNP) | VAF 28/554 reads (5%) | SIFT tolerated (0.27); PolyPhen benign (0.078); called by muse, mutect2
- OGA | c.397T>C p.F133L | Missense Mutation (SNP) | VAF 20/366 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.951); called by muse, mutect2
- OR10A6 | c.230T>A p.I77N | Missense Mutation (SNP) | VAF 26/695 reads (4%) | SIFT deleterious (0.03); PolyPhen benign (0.398); called by muse, mutect2
- OR10D3 | c.854C>T p.P285L | Missense Mutation (SNP) | VAF 15/417 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2
- OR1C1 | c.41T>C p.L14P | Missense Mutation (SNP) | VAF 14/368 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- OR1S2 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 22/616 reads (4%) | SIFT tolerated (1); PolyPhen benign (0.048); called by muse, mutect2
- OR2AG2 | c.860C>T p.P287L | Missense Mutation (SNP) | VAF 27/638 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- OR2T1 | c.221C>T p.S74F | Missense Mutation (SNP) | VAF 29/739 reads (4%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.769); called by muse, mutect2
- OR3A1 | c.488C>T p.T163I | Missense Mutation (SNP) | VAF 31/674 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- OR4D10 | c.610G>A p.G204R | Missense Mutation (SNP) | VAF 24/511 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR52N1 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 24/402 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR6M1 | c.134C>T p.S45F | Missense Mutation (SNP) | VAF 22/530 reads (4%) | SIFT tolerated (0.72); PolyPhen benign (0); called by muse, mutect2
- OR7E24 | c.839C>T p.S280L | Missense Mutation (SNP) | VAF 24/487 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- OR7E24 | c.1015G>A p.G339R | Missense Mutation (SNP) | VAF 11/176 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); called by muse, mutect2
- PACS2 | c.2120C>T p.S707F | Missense Mutation (SNP) | VAF 34/667 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.992); called by muse, mutect2
- PAK1 | c.150G>C p.K50N | Missense Mutation (SNP) | VAF 18/441 reads (4%) | SIFT tolerated (0.12); PolyPhen benign (0.185); called by muse, mutect2
- PAPOLB | c.146C>T p.P49L | Missense Mutation (SNP) | VAF 22/505 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.987); called by muse, mutect2
- PAPPA2 | c.1444C>T p.Q482* | Nonsense Mutation (SNP) | VAF 29/514 reads (6%) | called by muse, mutect2
- PCDH15 | c.37T>A p.S13T | Missense Mutation (SNP) | VAF 25/394 reads (6%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.084); called by muse, mutect2
- PCDHGA2 | c.2080G>A p.V694M | Missense Mutation (SNP) | VAF 43/941 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.766); called by muse, mutect2
- PCDHGA7 | c.1679C>T p.P560L | Missense Mutation (SNP) | VAF 40/590 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PCDHGB6 | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 26/578 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2
- PCLO | c.12904G>A p.D4302N | Missense Mutation (SNP) | VAF 39/400 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PDGFC | c.811T>C p.W271R | Missense Mutation (SNP) | VAF 30/542 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PDZD3 | c.181C>T p.P61S | Missense Mutation (SNP) | VAF 24/522 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.001); called by muse, mutect2
- PDZRN3 | c.1073C>T p.T358I | Missense Mutation (SNP) | VAF 15/532 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- PDZRN4 | c.2276C>T p.S759F (on ENST00000402685 / NM_001164595.2; = p.S501F on NM_013377.4) | Missense Mutation (SNP) | VAF 22/402 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- PI4KA | c.4865C>T p.S1622F | Missense Mutation (SNP) | VAF 36/683 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- PIP5KL1 | c.305G>A p.G102D | Missense Mutation (SNP) | VAF 56/642 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2
- PKM | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 28/511 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2
- PRRT2 | c.811C>T p.L271F | Missense Mutation (SNP) | VAF 45/692 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- PRSS38 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 38/676 reads (6%) | called by muse, mutect2
- PTGER4 | c.70C>T p.P24S | Missense Mutation (SNP) | VAF 25/508 reads (5%) | SIFT tolerated (0.11); PolyPhen benign (0.147); called by muse, mutect2
- PTH1R | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 50/826 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2
- PTPN4 | c.440C>T p.A147V | Missense Mutation (SNP) | VAF 30/447 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.158); called by muse, mutect2
- PTPRS | c.4666C>T p.P1556S | Missense Mutation (SNP) | VAF 34/550 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- QSOX1 | c.1589T>A p.F530Y | Missense Mutation (SNP) | VAF 30/614 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); called by muse, mutect2
- RAB3B | c.371C>T p.S124F | Missense Mutation (SNP) | VAF 21/400 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RASAL3 | c.2510G>A p.R837Q | Missense Mutation (SNP) | VAF 33/861 reads (4%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.749); called by muse, mutect2
- RBBP8NL | c.386G>A p.G129E | Missense Mutation (SNP) | VAF 32/465 reads (7%) | SIFT tolerated (1); PolyPhen benign (0.033); called by muse, mutect2
- RBM10 | c.1315C>T p.Q439* | Nonsense Mutation (SNP) | VAF 30/563 reads (5%) | called by muse, mutect2
- RET | c.2446C>T p.L816F | Missense Mutation (SNP) | VAF 50/712 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RFPL2 | c.1036C>T p.P346S | Missense Mutation (SNP) | VAF 16/352 reads (5%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); called by muse, mutect2
- RGS7 | c.91A>T p.I31L | Missense Mutation (SNP) | VAF 19/304 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.18); called by muse, mutect2
- RILPL1 | c.952G>A p.E318K | Missense Mutation (SNP) | VAF 18/380 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- RNF180 | c.1769T>G p.F590C | Missense Mutation (SNP) | VAF 16/245 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- RNF44 | c.866C>T p.P289L | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT tolerated (0.11); PolyPhen benign (0.177); called by muse, mutect2
- RPAP1 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 37/584 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.197); called by muse, mutect2
- RPAP2 | c.454C>T p.P152S | Missense Mutation (SNP) | VAF 22/382 reads (6%) | SIFT tolerated (0.92); PolyPhen benign (0.021); called by muse, mutect2
- RTL1 | c.359G>A p.R120K | Missense Mutation (SNP) | VAF 50/617 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); called by muse, mutect2
- RTTN | c.2195C>T p.P732L | Missense Mutation (SNP) | VAF 24/401 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.036); called by muse, mutect2
- RUBCN | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 67/646 reads (10%) | SIFT tolerated (0.05); PolyPhen benign (0.343); called by muse, mutect2, varscan2
- SCGB3A1 | c.40T>G p.S14A | Missense Mutation (SNP) | VAF 33/526 reads (6%) | SIFT tolerated (0.27); PolyPhen benign (0.154); called by muse, mutect2
- SCGB3A2 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 22/493 reads (4%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.61); called by muse, mutect2
- SCN2A | c.5440G>A p.E1814K | Missense Mutation (SNP) | VAF 22/618 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.296); called by muse, mutect2
- SDK1 | c.5615G>A p.G1872E | Missense Mutation (SNP) | VAF 31/526 reads (6%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.489); called by muse, mutect2
- SEZ6L2 | c.1499C>T p.P500L (on ENST00000308713 / NM_001114099.3; = p.P430L on NM_012410.4) | Missense Mutation (SNP) | VAF 30/636 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.84); called by muse, mutect2
- SHISA9 | c.1183G>A p.G395S | Missense Mutation (SNP) | VAF 28/660 reads (4%) | SIFT tolerated (0.44); PolyPhen benign (0); called by muse, mutect2
- SHROOM4 | c.4345C>T p.Q1449* | Nonsense Mutation (SNP) | VAF 27/802 reads (3%) | called by muse, mutect2
- SLC25A12 | c.1765C>T p.P589S | Missense Mutation (SNP) | VAF 26/422 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2
- SLC2A5 | c.1169G>A p.G390E | Missense Mutation (SNP) | VAF 28/398 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLC35E1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 33/537 reads (6%) | SIFT tolerated, low confidence (0.14); PolyPhen possibly damaging (0.537); called by muse, mutect2
- SLC4A8 | c.1391C>T p.P464L | Missense Mutation (SNP) | VAF 22/442 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- SLCO4C1 | c.724G>A p.G242R | Missense Mutation (SNP) | VAF 28/548 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SMYD1 | c.52G>A p.G18R | Missense Mutation (SNP) | VAF 29/597 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNCAIP | c.995C>T p.S332F | Missense Mutation (SNP) | VAF 12/269 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- SOX5 | c.2120C>T p.P707L | Missense Mutation (SNP) | VAF 30/578 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by muse, mutect2
- SPANXN2 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 28/631 reads (4%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); called by muse, mutect2
- SPEF2 | c.250G>A p.G84S | Missense Mutation (SNP) | VAF 20/644 reads (3%) | SIFT tolerated (0.82); PolyPhen benign (0.005); called by muse, mutect2
- SPP1 | c.391G>A p.E131K (on ENST00000395080 / NM_001040058.2; = p.E117K on NM_000582.2) | Missense Mutation (SNP) | VAF 30/478 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- STARD9 | c.5213C>T p.S1738F | Missense Mutation (SNP) | VAF 46/582 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.637); called by muse, mutect2
- STRADB | c.74C>T p.T25I | Missense Mutation (SNP) | VAF 16/366 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0); called by muse, mutect2
- SYTL5 | c.1669G>A p.E557K | Missense Mutation (SNP) | VAF 24/420 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.007); called by muse, mutect2
- TACC2 | c.2747C>T p.S916L | Missense Mutation (SNP) | VAF 23/515 reads (4%) | SIFT tolerated (0.18); PolyPhen benign (0.009); called by muse, mutect2
- TDRD15 | c.2354T>G p.L785R | Missense Mutation (SNP) | VAF 19/444 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- TG | c.7334C>T p.S2445L | Missense Mutation (SNP) | VAF 30/618 reads (5%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.831); called by muse, mutect2
- TIAM2 | c.824C>T p.P275L | Missense Mutation (SNP) | VAF 17/490 reads (3%) | SIFT deleterious (0.03); PolyPhen benign (0.058); called by muse, mutect2
- TIE1 | c.215C>T p.T72I | Missense Mutation (SNP) | VAF 28/849 reads (3%) | SIFT tolerated (0.08); PolyPhen benign (0.058); called by muse, mutect2
- TLX1 | c.299C>T p.S100F | Missense Mutation (SNP) | VAF 26/684 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.496); called by muse, mutect2
- TMIGD2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 24/486 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.841); called by muse, mutect2
- TMPRSS15 | c.2637G>A p.M879I | Missense Mutation (SNP) | VAF 20/404 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.146); called by muse, mutect2
- TMPRSS9 | c.1970G>A p.G657D (on ENST00000648592; = p.G623D on NM_182973.2) | Missense Mutation (SNP) | VAF 40/564 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- TNNI3 | c.604G>A p.E202K | Missense Mutation (SNP) | VAF 16/456 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2
- TNRC6B | c.3560C>T p.P1187L | Missense Mutation (SNP) | VAF 19/404 reads (5%) | SIFT tolerated (0.54); PolyPhen probably damaging (0.987); called by muse, mutect2
- TNXB | c.10057G>A p.V3353M (on ENST00000647633; = p.V3106M on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 39/804 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2
- TOGARAM2 | c.619T>A p.L207M | Missense Mutation (SNP) | VAF 28/488 reads (6%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.556); called by muse, mutect2
- TP63 | c.520C>T p.P174S | Missense Mutation (SNP) | VAF 29/730 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.976); called by muse, mutect2
- TRAV12-3 | c.38G>A p.W13* | Nonsense Mutation (SNP) | VAF 24/444 reads (5%) | called by muse, mutect2
- TRAV9-1 | c.289G>A p.D97N | Missense Mutation (SNP) | VAF 21/359 reads (6%) | SIFT tolerated (0.15); PolyPhen benign (0.102); called by muse, mutect2
- TRIO | c.8902C>T p.P2968S | Missense Mutation (SNP) | VAF 30/650 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2
- TRPV6 | c.889C>T p.Q297* | Nonsense Mutation (SNP) | VAF 34/373 reads (9%) | called by muse, mutect2
- TTC28 | c.2606G>A p.G869E | Missense Mutation (SNP) | VAF 29/577 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.871); called by muse, mutect2
- TTN | c.69428G>A p.G23143D (on ENST00000591111; = p.G15719D on NM_003319.4) | Missense Mutation (SNP) | VAF 24/496 reads (5%) | PolyPhen possibly damaging (0.878); called by muse, mutect2
- TTN | c.15721G>C p.G5241R (on ENST00000591111; = p.G4314R on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/555 reads (4%) | PolyPhen probably damaging (0.973); called by muse, mutect2
- UBQLNL | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 35/549 reads (6%) | called by muse, mutect2
- UNC80 | c.3179C>T p.T1060I | Missense Mutation (SNP) | VAF 31/701 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.311); called by muse, mutect2
- UPB1 | c.140C>T p.A47V | Missense Mutation (SNP) | VAF 24/438 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.884); called by muse, mutect2
- URB2 | c.3421C>T p.Q1141* | Nonsense Mutation (SNP) | VAF 27/630 reads (4%) | called by muse, mutect2
- USH1G | c.307G>A p.D103N | Missense Mutation (SNP) | VAF 26/564 reads (5%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.995); called by muse, mutect2
- USH1G | c.230A>C p.H77P | Missense Mutation (SNP) | VAF 24/570 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- USP27X | c.925C>T p.H309Y | Missense Mutation (SNP) | VAF 25/538 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- UTP6 | c.1747G>A p.E583K | Missense Mutation (SNP) | VAF 19/429 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.258); called by muse, mutect2
- WDR12 | c.1208G>A p.G403E | Missense Mutation (SNP) | VAF 14/232 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2
- WWC2 | c.2777T>C p.L926S | Missense Mutation (SNP) | VAF 38/674 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0); called by muse, mutect2
- XIRP1 | c.1444C>T p.P482S | Missense Mutation (SNP) | VAF 38/694 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.284); called by muse, mutect2
- YLPM1 | c.1492G>C p.E498Q | Missense Mutation (SNP) | VAF 26/604 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.43); called by muse, mutect2
- ZEB2 | c.3506A>T p.N1169I | Missense Mutation (SNP) | VAF 26/595 reads (4%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.795); called by muse, mutect2
- ZFHX2 | c.6158C>T p.P2053L | Missense Mutation (SNP) | VAF 30/581 reads (5%) | SIFT tolerated (0.13); PolyPhen benign (0); called by muse, mutect2
- ZNF233 | c.1342G>A p.G448R | Missense Mutation (SNP) | VAF 19/546 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2
- ZNF273 | c.1522C>T p.H508Y | Missense Mutation (SNP) | VAF 20/423 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.537); called by muse, mutect2
- ZNF334 | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 22/534 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2
- ZNF442 | c.1583T>G p.F528C | Missense Mutation (SNP) | VAF 17/452 reads (4%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.784); called by muse, mutect2
- ZNF479 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 20/493 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- ZNF512B | c.1709C>T p.A570V | Missense Mutation (SNP) | VAF 18/514 reads (4%) | SIFT tolerated (0.75); PolyPhen benign (0.075); called by muse, mutect2
- ZNF622 | c.898G>A p.G300S | Missense Mutation (SNP) | VAF 14/339 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); called by muse, mutect2
- ZNF668 | c.1304C>T p.P435L | Missense Mutation (SNP) | VAF 31/683 reads (5%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.133); called by muse, mutect2
- ZNF722P | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 11/270 reads (4%) | SIFT tolerated (0.27); PolyPhen benign (0.092); called by muse, mutect2
- ZNF727 | c.1324C>T p.H442Y | Missense Mutation (SNP) | VAF 32/635 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.775); called by muse, mutect2
- ZNF786 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 50/685 reads (7%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2
- ZNF841 | c.1750C>T p.H584Y (on ENST00000426391 / NM_001369830.1; = p.H700Y on NM_001136499.1 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 20/607 reads (3%) | SIFT deleterious (0.05); PolyPhen benign (0.125); called by muse, mutect2
- ZRANB3 | c.563G>A p.G188E | Missense Mutation (SNP) | VAF 17/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ZSCAN20 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 14/358 reads (4%) | SIFT tolerated (0.63); PolyPhen benign (0.015); called by muse, mutect2
- ABCB10 | c.660C>T p.A220= | Silent (SNP) | VAF 39/534 reads (7%) | catalogued as rs1412778261; called by muse, mutect2
- ABCC6 | c.1543C>T p.L515= | Silent (SNP) | VAF 36/854 reads (4%) | called by muse, mutect2
- ACSM1 | c.756G>A p.R252= | Silent (SNP) | VAF 12/188 reads (6%) | catalogued as COSV54638311; called by muse, mutect2
- ADAMTS10 | c.2379G>A p.P793= | Silent (SNP) | VAF 24/481 reads (5%) | catalogued as rs1363240605; called by muse, mutect2
- ADAT1 | c.258C>T p.S86= | Silent (SNP) | VAF 16/496 reads (3%) | called by muse, mutect2
- ADCY8 | c.918C>T p.L306= | Silent (SNP) | VAF 26/474 reads (5%) | called by muse, mutect2
- ADCY9 | c.1437G>A p.E479= | Silent (SNP) | VAF 28/602 reads (5%) | called by muse, mutect2
- ADGB | c.3504C>T p.I1168= | Silent (SNP) | VAF 17/453 reads (4%) | called by muse, mutect2
- ADGRG1 | c.1995C>T p.A665= | Silent (SNP) | VAF 24/572 reads (4%) | catalogued as rs1567832419; called by muse, mutect2
- ADORA2A | c.1209C>T p.P403= | Silent (SNP) | VAF 20/571 reads (4%) | catalogued as COSV58380937; called by muse, mutect2
- ADPRHL1 | c.5838G>A p.R1946= | Silent (SNP) | VAF 31/426 reads (7%) | called by muse, mutect2
- ADPRHL1 | c.408C>T p.A136= | Silent (SNP) | VAF 24/417 reads (6%) | called by muse, mutect2
- AL121899.2 | c.2121C>T p.S707= | Silent (SNP) | VAF 19/389 reads (5%) | catalogued as rs1024562956, COSV67350766; called by muse, mutect2
- ANKRD62 | c.1989C>T p.A663= | Silent (SNP) | VAF 26/563 reads (5%) | catalogued as rs1307434396; called by muse, mutect2
- ANKRD65 | c.243C>T p.A81= | Silent (SNP) | VAF 36/588 reads (6%) | called by muse, mutect2
- ANKS3 | c.753T>G p.A251= | Silent (SNP) | VAF 34/529 reads (6%) | called by muse, mutect2
- AP2A2 | c.1830C>T p.S610= | Silent (SNP) | VAF 48/819 reads (6%) | called by muse, mutect2
- AR | c.2025G>A p.L675= | Silent (SNP) | VAF 29/648 reads (4%) | catalogued as COSV101018668; called by muse, mutect2
- ARHGAP22 | c.132G>A p.L44= | Silent (SNP) | VAF 46/694 reads (7%) | catalogued as COSV99985320; called by muse, mutect2
- ASPM | c.5814G>A p.R1938= | Silent (SNP) | VAF 23/575 reads (4%) | catalogued as COSV54129660; called by muse, mutect2
- ATG2A | c.3996C>T p.G1332= | Silent (SNP) | VAF 37/680 reads (5%) | called by muse, mutect2
- B3GNTL1 | c.777C>T p.P259= | Silent (SNP) | VAF 36/586 reads (6%) | called by muse, mutect2
- BAIAP2 | c.1398C>T p.I466= | Silent (SNP) | VAF 41/745 reads (6%) | called by muse, mutect2
- BDNF | c.462G>A p.K154= | Silent (SNP) | VAF 24/536 reads (4%) | called by muse, mutect2
- BRPF3 | c.357C>T p.F119= | Silent (SNP) | VAF 24/669 reads (4%) | called by muse, mutect2
- BTBD8 | c.1947G>A p.R649= (on ENST00000636805 / NM_001376131.1; = p.R136= on NM_015237.4) | Silent (SNP) | VAF 36/534 reads (7%) | catalogued as rs910228114; called by muse, mutect2
- C17orf97 | c.678C>T p.H226= | Silent (SNP) | VAF 42/545 reads (8%) | catalogued as rs782428788, COSV64077407; called by muse, mutect2
- C4orf19 | c.435G>A p.Q145= | Silent (SNP) | VAF 36/670 reads (5%) | catalogued as rs1276958187; called by muse, mutect2
- CABP4 | c.510C>T p.L170= | Silent (SNP) | VAF 34/561 reads (6%) | catalogued as rs1322254399; called by muse, mutect2
- CACNA1I | c.1626C>T p.I542= | Silent (SNP) | VAF 40/598 reads (7%) | called by muse, mutect2
- CACNA1S | c.3198C>T p.V1066= | Silent (SNP) | VAF 18/462 reads (4%) | called by muse, mutect2
- CAD | c.5892C>T p.V1964= | Silent (SNP) | VAF 19/403 reads (5%) | catalogued as rs1205585536; called by muse, mutect2
- CASKIN1 | c.2328C>T p.P776= | Silent (SNP) | VAF 46/895 reads (5%) | catalogued as rs1001277690; called by muse, mutect2
- CCDC8 | c.468C>T p.F156= | Silent (SNP) | VAF 29/598 reads (5%) | called by muse, mutect2
- CCL3L3 | c.279C>T p.A93= | Silent (SNP) | VAF 22/529 reads (4%) | called by muse, mutect2
- CCNL2 | c.1257C>T p.S419= | Silent (SNP) | VAF 28/506 reads (6%) | called by muse, mutect2
- CD163 | c.528C>T p.F176= | Silent (SNP) | VAF 26/560 reads (5%) | catalogued as COSV63132363; called by muse, mutect2
- CDH22 | c.831C>T p.F277= | Silent (SNP) | VAF 22/376 reads (6%) | catalogued as COSV64839334; called by muse, mutect2
- CDHR1 | c.2313G>A p.E771= | Silent (SNP) | VAF 31/624 reads (5%) | called by muse, mutect2
- CDRT1 | c.1626C>T p.I542= | Silent (SNP) | VAF 26/525 reads (5%) | called by muse, mutect2
- CDSN | c.972C>T p.F324= | Silent (SNP) | VAF 44/915 reads (5%) | catalogued as COSV99456984; called by muse, mutect2
- CENPE | c.2800C>T p.L934= | Silent (SNP) | VAF 16/370 reads (4%) | called by muse, mutect2
- CEP250 | c.6840C>T p.A2280= | Silent (SNP) | VAF 39/618 reads (6%) | catalogued as COSV100698765; called by muse, mutect2
- CFAP47 | c.7044T>C p.F2348= | Silent (SNP) | VAF 19/380 reads (5%) | called by muse, mutect2
- CGN | c.2649C>T p.A883= | Silent (SNP) | VAF 27/552 reads (5%) | called by muse, mutect2
- CLSTN2 | c.2571C>T p.I857= | Silent (SNP) | VAF 46/696 reads (7%) | catalogued as rs766225194; called by muse, mutect2
- CLTC | c.3933A>T p.R1311= | Silent (SNP) | VAF 17/381 reads (4%) | called by muse, mutect2
- COL11A2 | c.2496G>A p.G832= (on ENST00000341947 / NM_080680.3; = p.G725= on NM_080679.2) | Silent (SNP) | VAF 43/836 reads (5%) | called by muse, mutect2
- COL6A6 | c.4854C>T p.G1618= | Silent (SNP) | VAF 23/443 reads (5%) | called by muse, mutect2
- COPZ2 | c.48C>T p.A16= | Silent (SNP) | VAF 16/283 reads (6%) | called by muse, mutect2
- CSMD2 | c.4908C>T p.P1636= | Silent (SNP) | VAF 14/386 reads (4%) | catalogued as COSV99585609; called by muse, mutect2
- CSPG4 | c.2877C>T p.S959= | Silent (SNP) | VAF 20/578 reads (3%) | catalogued as rs1189335508; called by muse, mutect2
- CTNNA2 | c.2631C>T p.V877= (on ENST00000402739 / NM_001282597.3; = p.V829= on NM_004389.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 15/320 reads (5%) | catalogued as COSV58135116; called by muse, mutect2
- CUX2 | c.2757C>T p.F919= | Silent (SNP) | VAF 16/320 reads (5%) | catalogued as COSV55633405; called by muse, mutect2
- CYRIA | c.57C>T p.F19= | Silent (SNP) | VAF 14/277 reads (5%) | catalogued as COSV62867501; called by muse, mutect2
- DCLK3 | c.624G>A p.R208= | Silent (SNP) | VAF 19/588 reads (3%) | catalogued as COSV69362467; called by muse, mutect2
- DCPS | c.292C>T p.L98= | Silent (SNP) | VAF 21/549 reads (4%) | catalogued as COSV55012597; called by muse, mutect2
- DNAH17 | c.2107C>T p.L703= | Silent (SNP) | VAF 26/588 reads (4%) | called by muse, mutect2
- DRP2 | c.2037C>T p.S679= | Silent (SNP) | VAF 42/550 reads (8%) | called by muse, mutect2
- DSG2 | c.3216G>A p.R1072= | Silent (SNP) | VAF 29/462 reads (6%) | catalogued as rs1289097014; called by muse, mutect2
- DTNB | c.276G>A p.L92= | Silent (SNP) | VAF 19/439 reads (4%) | called by muse, mutect2
- EFCAB8 | c.3750C>T p.S1250= | Silent (SNP) | VAF 23/543 reads (4%) | called by muse, mutect2
- EGFLAM | c.2406G>A p.R802= | Silent (SNP) | VAF 24/592 reads (4%) | called by muse, mutect2
- EGFLAM | c.2964C>T p.I988= (on ENST00000354891 / NM_001205301.2; = p.I980= on NM_152403.4) | Silent (SNP) | VAF 26/522 reads (5%) | catalogued as rs1277196049, COSV59293920; called by muse, mutect2
- ELFN2 | c.1173C>T p.T391= | Silent (SNP) | VAF 36/622 reads (6%) | called by muse, mutect2
- EMC6 | c.306C>T p.F102= | Silent (SNP) | VAF 19/401 reads (5%) | called by muse, mutect2
- EML6 | c.1380C>T p.S460= | Silent (SNP) | VAF 28/500 reads (6%) | called by muse, mutect2
- EPHA1 | c.111G>A p.Q37= | Silent (SNP) | VAF 38/524 reads (7%) | called by muse, mutect2
- EPS15L1 | c.1659C>T p.S553= | Silent (SNP) | VAF 27/473 reads (6%) | called by muse, mutect2
- F13A1 | c.1593A>T p.G531= | Silent (SNP) | VAF 42/685 reads (6%) | called by muse, mutect2
- FAM135B | c.2229C>T p.I743= | Silent (SNP) | VAF 19/521 reads (4%) | catalogued as rs1338500603, COSV52749985; called by muse, mutect2
- FAM83B | c.1377G>A p.R459= | Silent (SNP) | VAF 24/510 reads (5%) | catalogued as COSV60921971, COSV60925896; called by muse, mutect2
- FANCA | c.2442C>T p.V814= | Silent (SNP) | VAF 34/655 reads (5%) | called by muse, mutect2
- FASLG | c.300G>A p.G100= | Silent (SNP) | VAF 49/695 reads (7%) | catalogued as COSV60680882; called by muse, mutect2
- FGFR4 | c.546C>T p.I182= | Silent (SNP) | VAF 40/688 reads (6%) | catalogued as rs1171622730; called by muse, mutect2
- FRAS1 | c.5113C>T p.L1705= | Silent (SNP) | VAF 39/528 reads (7%) | catalogued as COSV99356895; called by muse, mutect2
- FRMD8 | c.816C>T p.F272= | Silent (SNP) | VAF 19/372 reads (5%) | called by muse, mutect2
- FTCD | c.933C>T p.S311= | Silent (SNP) | VAF 24/628 reads (4%) | catalogued as rs752384764, COSV52426818; called by muse, mutect2
- FZD10 | c.465G>A p.S155= | Silent (SNP) | VAF 25/568 reads (4%) | catalogued as rs1324470180, COSV57472461; called by muse, mutect2
- GAB4 | c.105G>A p.T35= | Silent (SNP) | VAF 46/638 reads (7%) | called by muse, mutect2
- GAL3ST1 | c.642C>T p.L214= | Silent (SNP) | VAF 22/521 reads (4%) | catalogued as rs1185905402; called by muse, mutect2
- GALK1 | c.831G>A p.R277= | Silent (SNP) | VAF 24/530 reads (5%) | called by muse, mutect2
- GALM | c.711C>T p.F237= | Silent (SNP) | VAF 20/360 reads (6%) | called by muse, mutect2
- GATA5 | c.540G>A p.E180= | Silent (SNP) | VAF 18/426 reads (4%) | catalogued as rs1555896800, COSV99435829; called by muse, mutect2
- GBP1 | c.729C>T p.H243= | Silent (SNP) | VAF 20/492 reads (4%) | called by muse, mutect2
- GFY | c.972A>C p.S324= | Silent (SNP) | VAF 42/680 reads (6%) | called by muse, mutect2
- GIMAP6 | c.405C>T p.F135= | Silent (SNP) | VAF 50/632 reads (8%) | catalogued as rs1212155268, COSV61033530; called by muse, mutect2
- GIMAP8 | c.1491C>T p.F497= | Silent (SNP) | VAF 32/590 reads (5%) | called by muse, mutect2
- GLP2R | c.1399C>T p.L467= | Silent (SNP) | VAF 26/517 reads (5%) | called by muse, mutect2
- GRK1 | c.1569C>T p.I523= | Silent (SNP) | VAF 30/648 reads (5%) | catalogued as rs867427547, COSV59551655; called by muse, mutect2
- GRK2 | c.1747C>T p.L583= | Silent (SNP) | VAF 38/670 reads (6%) | called by muse, mutect2
- GRM5 | c.2643G>A p.R881= | Silent (SNP) | VAF 18/428 reads (4%) | catalogued as COSV59621466; called by muse, mutect2
- GTF2H4 | c.669C>T p.A223= | Silent (SNP) | VAF 32/510 reads (6%) | called by muse, mutect2
- H2BC21 | c.210C>T p.I70= | Silent (SNP) | VAF 46/704 reads (7%) | catalogued as rs1225639259; called by muse, mutect2
- HEATR3 | c.1818C>T p.A606= | Silent (SNP) | VAF 25/524 reads (5%) | catalogued as COSV53531607; called by muse, mutect2
- HIPK3 | c.2853C>T p.G951= | Silent (SNP) | VAF 16/381 reads (4%) | called by muse, mutect2
- HSPG2 | c.2490C>T p.F830= | Silent (SNP) | VAF 34/532 reads (6%) | catalogued as COSV101020519; called by muse, mutect2
- HUWE1 | c.11865C>T p.F3955= | Silent (SNP) | VAF 25/282 reads (9%) | called by muse, mutect2
- ICAM1 | c.46C>T p.L16= | Silent (SNP) | VAF 26/640 reads (4%) | called by muse, mutect2
- IGKV4-1 | c.135C>T p.S45= | Silent (SNP) | VAF 30/370 reads (8%) | catalogued as rs1157384463; called by muse, mutect2
- IL1A | c.234G>A p.G78= | Silent (SNP) | VAF 25/592 reads (4%) | catalogued as COSV54518995; called by muse, mutect2
- INSRR | c.3034C>T p.L1012= | Silent (SNP) | VAF 29/594 reads (5%) | called by muse, mutect2
- INSRR | c.3033C>T p.A1011= | Silent (SNP) | VAF 28/588 reads (5%) | called by muse, mutect2
- IQCA1L | c.286C>T p.L96= | Silent (SNP) | VAF 42/604 reads (7%) | called by muse, mutect2
- ITM2C | c.310C>T p.L104= | Silent (SNP) | VAF 25/612 reads (4%) | called by muse, mutect2
- KAAG1 | c.120C>T p.R40= | Silent (SNP) | VAF 38/648 reads (6%) | called by muse, mutect2
- KCNK10 | c.1320G>A p.E440= | Silent (SNP) | VAF 33/530 reads (6%) | called by muse, mutect2
- KIF1B | c.4449C>T p.P1483= (on ENST00000377086 / NM_001365952.1; = p.P1437= on NM_015074.3) | Silent (SNP) | VAF 24/538 reads (4%) | called by muse, mutect2
- KMT2C | c.4626C>T p.P1542= | Silent (SNP) | VAF 22/374 reads (6%) | called by muse, mutect2
- LHCGR | c.1878C>T p.F626= | Silent (SNP) | VAF 22/451 reads (5%) | catalogued as COSV54301718; called by muse, mutect2
- LIPT2 | c.63G>C p.G21= | Silent (SNP) | VAF 36/620 reads (6%) | called by muse, mutect2
- LONRF2 | c.477G>A p.G159= | Silent (SNP) | VAF 24/556 reads (4%) | called by muse, mutect2
- LPAR4 | c.663C>T p.V221= | Silent (SNP) | VAF 24/590 reads (4%) | catalogued as COSV70913500; called by muse, mutect2
- LPIN3 | c.2391C>T p.L797= | Silent (SNP) | VAF 19/406 reads (5%) | catalogued as COSV60039193; called by muse, mutect2
- LRCOL1 | c.228G>A p.R76= | Silent (SNP) | VAF 16/350 reads (5%) | called by muse, mutect2
- LRRK1 | c.474C>T p.A158= | Silent (SNP) | VAF 34/626 reads (5%) | called by muse, mutect2
- LUC7L | c.816C>T p.S272= | Silent (SNP) | VAF 26/471 reads (6%) | called by muse, mutect2
- LYPD5 | c.243T>G p.P81= (on ENST00000377950 / NM_001031749.3; = p.P38= on NM_182573.2) | Silent (SNP) | VAF 36/698 reads (5%) | called by muse, mutect2
- MAB21L3 | c.747G>A p.L249= | Silent (SNP) | VAF 24/437 reads (5%) | catalogued as rs1261754261; called by muse, mutect2
- MAP3K11 | c.1947C>T p.T649= | Silent (SNP) | VAF 40/813 reads (5%) | catalogued as rs926592880; called by muse, mutect2
- MAPK4 | c.1470C>T p.F490= | Silent (SNP) | VAF 32/652 reads (5%) | called by muse, mutect2
- MARK2 | c.1497C>T p.I499= (on ENST00000402010 / NM_001039469.2; = p.I498= on NM_004954.5) | Silent (SNP) | VAF 26/431 reads (6%) | catalogued as rs1299189299; called by muse, mutect2
- MEF2B | c.867C>T p.P289= | Silent (SNP) | VAF 32/658 reads (5%) | called by muse, mutect2
- MEFV | c.876G>A p.K292= | Silent (SNP) | VAF 22/448 reads (5%) | called by muse, mutect2
- MELTF | c.2022G>A p.K674= | Silent (SNP) | VAF 28/592 reads (5%) | called by muse, mutect2
- MGAM2 | c.2913C>T p.S971= | Silent (SNP) | VAF 40/570 reads (7%) | catalogued as rs1304323734; called by muse, mutect2
- MPL | c.126C>T p.S42= | Silent (SNP) | VAF 30/476 reads (6%) | called by muse, mutect2
- MROH1 | c.1059C>T p.F353= | Silent (SNP) | VAF 24/462 reads (5%) | catalogued as rs1354207573; called by muse, mutect2
- MROH2B | c.2869C>T p.L957= | Silent (SNP) | VAF 16/374 reads (4%) | catalogued as rs865914670; called by muse, mutect2
- MUC22 | c.1866C>T p.G622= | Silent (SNP) | VAF 36/958 reads (4%) | called by muse, mutect2
- MUC22 | c.4434C>T p.P1478= | Silent (SNP) | VAF 25/567 reads (4%) | called by muse, mutect2
- MYH11 | c.3903G>A p.G1301= | Silent (SNP) | VAF 20/508 reads (4%) | called by muse, mutect2
- MYH6 | c.1221G>A p.V407= | Silent (SNP) | VAF 26/694 reads (4%) | called by muse, mutect2
- MYL9 | c.402C>T p.F134= | Silent (SNP) | VAF 23/481 reads (5%) | catalogued as COSV54072205; called by muse, mutect2
- MYO5B | c.2941C>T p.L981= | Silent (SNP) | VAF 36/610 reads (6%) | catalogued as COSV53213420; called by muse, mutect2
- MYO9B | c.2559C>T p.I853= | Silent (SNP) | VAF 16/386 reads (4%) | called by muse, mutect2
- NAT10 | c.1335G>A p.E445= | Silent (SNP) | VAF 22/414 reads (5%) | called by muse, mutect2
- NFKBIE | c.1266C>T p.F422= (on ENST00000275015; = p.F283= on NM_004556.3) | Silent (SNP) | VAF 20/642 reads (3%) | called by muse, mutect2
- NOC2L | c.336C>T p.S112= | Silent (SNP) | VAF 36/479 reads (8%) | called by muse, mutect2
- NOTCH1 | c.474C>T p.F158= | Silent (SNP) | VAF 64/670 reads (10%) | catalogued as rs774011231; called by muse, mutect2
- NPAP1 | c.2385T>A p.L795= | Silent (SNP) | VAF 23/580 reads (4%) | called by muse, mutect2
- NPC1L1 | c.3904C>T p.L1302= | Silent (SNP) | VAF 26/474 reads (5%) | called by muse, mutect2
- NR2E1 | c.682C>T p.L228= | Silent (SNP) | VAF 16/372 reads (4%) | catalogued as COSV64561694; called by muse, mutect2
- NRROS | c.588C>T p.I196= | Silent (SNP) | VAF 24/670 reads (4%) | catalogued as COSV60744707; called by muse, mutect2
- NUTM1 | c.2853G>A p.E951= | Silent (SNP) | VAF 22/472 reads (5%) | catalogued as COSV100148934; called by muse, mutect2
- ODC1 | c.228C>T p.I76= | Silent (SNP) | VAF 25/466 reads (5%) | catalogued as rs1359590938; called by muse, mutect2
- OPRD1 | c.549C>T p.I183= | Silent (SNP) | VAF 38/496 reads (8%) | called by muse, mutect2
- OR10J5 | c.726C>T p.S242= | Silent (SNP) | VAF 25/588 reads (4%) | called by muse, mutect2
- OR13C8 | c.762C>T p.T254= | Silent (SNP) | VAF 24/389 reads (6%) | called by muse, mutect2
- OR2AG2 | c.705G>A p.K235= | Silent (SNP) | VAF 33/606 reads (5%) | catalogued as COSV100643088; called by muse, mutect2
- OR2B11 | c.918G>A p.R306= | Silent (SNP) | VAF 17/376 reads (5%) | catalogued as rs1274757742; called by muse, mutect2
- OR2T11 | c.144G>A p.V48= | Silent (SNP) | VAF 38/536 reads (7%) | catalogued as COSV58185681; called by muse, mutect2
- OR51E1 | c.915C>T p.I305= | Silent (SNP) | VAF 16/432 reads (4%) | called by muse, mutect2
- OR5L2 | c.213C>T p.F71= | Silent (SNP) | VAF 25/611 reads (4%) | catalogued as COSV65723408; called by muse, mutect2
- OR6C70 | c.513C>T p.I171= | Silent (SNP) | VAF 15/348 reads (4%) | called by muse, mutect2
- OR9H1P | c.219C>T p.S73= | Silent (SNP) | VAF 18/496 reads (4%) | called by muse, mutect2
- OSBP2 | c.1009C>T p.L337= | Silent (SNP) | VAF 27/632 reads (4%) | called by muse, mutect2
- PAN2 | c.715C>T p.L239= | Silent (SNP) | VAF 17/567 reads (3%) | called by muse, mutect2
- PCDHA9 | c.1920G>A p.T640= | Silent (SNP) | VAF 28/620 reads (5%) | catalogued as rs782097417, COSV65324535; called by muse, mutect2
- PCDHAC1 | c.208C>T p.L70= | Silent (SNP) | VAF 42/520 reads (8%) | catalogued as COSV99169710; called by muse, mutect2
- PCDHGA2 | c.1686C>T p.I562= | Silent (SNP) | VAF 21/749 reads (3%) | catalogued as COSV53982738; called by muse, mutect2
- PCDHGA6 | c.2310C>T p.F770= | Silent (SNP) | VAF 25/449 reads (6%) | catalogued as COSV53952971, COSV53998154; called by muse, mutect2
- PCDHGB2 | c.840C>T p.S280= | Silent (SNP) | VAF 28/544 reads (5%) | called by muse, mutect2
- PDLIM7 | c.1065C>T p.A355= | Silent (SNP) | VAF 17/391 reads (4%) | catalogued as rs1464398624; called by muse, mutect2
- PEX16 | c.234C>T p.S78= | Silent (SNP) | VAF 25/343 reads (7%) | called by muse, mutect2
- PHKA1 | c.1257C>T p.A419= | Silent (SNP) | VAF 26/452 reads (6%) | called by muse, mutect2
- PLEC | c.2091C>T p.G697= (on ENST00000322810 / NM_201380.4; = p.G587= on NM_000445.5) | Silent (SNP) | VAF 42/616 reads (7%) | called by muse, mutect2
- PLEKHG2 | c.3903C>T p.P1301= | Silent (SNP) | VAF 38/620 reads (6%) | catalogued as rs1221915379, COSV52684190; called by muse, mutect2
- PM20D1 | c.807C>T p.I269= | Silent (SNP) | VAF 19/351 reads (5%) | called by muse, mutect2
- PML | c.2061C>T p.F687= | Silent (SNP) | VAF 22/542 reads (4%) | called by muse, mutect2
- POGLUT1 | c.1065C>T p.I355= | Silent (SNP) | VAF 27/462 reads (6%) | called by muse, mutect2
- PPM1L | c.706T>C p.L236= | Silent (SNP) | VAF 25/409 reads (6%) | catalogued as COSV55564897; called by muse, mutect2
- PRAMEF4 | c.601C>T p.L201= | Silent (SNP) | VAF 21/706 reads (3%) | catalogued as rs1187949787; called by muse, mutect2
- PRDM15 | c.3387C>T p.I1129= | Silent (SNP) | VAF 34/602 reads (6%) | called by muse, mutect2
- PRKCZ | c.1359C>T p.I453= | Silent (SNP) | VAF 20/521 reads (4%) | catalogued as rs1405309367; called by muse, mutect2
- PROB1 | c.2682G>A p.V894= | Silent (SNP) | VAF 40/653 reads (6%) | called by muse, mutect2
- PROM2 | c.1194C>T p.S398= | Silent (SNP) | VAF 28/584 reads (5%) | called by muse, mutect2
- PRPS1L1 | c.726C>T p.T242= | Silent (SNP) | VAF 18/485 reads (4%) | called by muse, mutect2
- PYGM | c.807C>T p.D269= | Silent (SNP) | VAF 24/401 reads (6%) | called by muse, mutect2
- RAB11B | c.453C>T p.I151= | Silent (SNP) | VAF 25/552 reads (5%) | catalogued as rs937126014, COSV60085397; called by muse, mutect2
- RBM47 | c.465C>T p.I155= | Silent (SNP) | VAF 29/636 reads (5%) | catalogued as rs1027590780, COSV55933150; called by muse, mutect2
- RHBDF2 | c.1950C>T p.V650= | Silent (SNP) | VAF 25/490 reads (5%) | called by muse, mutect2
- RNF10 | c.501G>A p.K167= | Silent (SNP) | VAF 24/489 reads (5%) | called by muse, mutect2
- RRAS2 | c.267C>T p.F89= | Silent (SNP) | VAF 27/465 reads (6%) | called by muse, mutect2
- RSPH14 | c.346C>T p.L116= | Silent (SNP) | VAF 25/404 reads (6%) | called by muse, mutect2
- SALL1 | c.1503G>A p.E501= | Silent (SNP) | VAF 20/447 reads (4%) | catalogued as COSV51752847, COSV51757832; called by muse, mutect2
- SBK2 | c.684C>T p.L228= | Silent (SNP) | VAF 49/850 reads (6%) | called by muse, mutect2
- SCRIB | c.1350C>T p.F450= | Silent (SNP) | VAF 33/673 reads (5%) | catalogued as rs748875240, COSV57581700; called by muse, mutect2
- SEMA6C | c.2664G>A p.R888= | Silent (SNP) | VAF 24/722 reads (3%) | catalogued as rs929009137; called by muse, mutect2
- SH3BP2 | c.1077C>T p.F359= | Silent (SNP) | VAF 42/765 reads (5%) | called by muse, mutect2
- SHROOM3 | c.1431T>C p.F477= | Silent (SNP) | VAF 24/554 reads (4%) | called by muse, mutect2
- SHROOM4 | c.4344C>T p.L1448= | Silent (SNP) | VAF 27/800 reads (3%) | called by muse, mutect2
- SIPA1L3 | c.981C>T p.P327= | Silent (SNP) | VAF 30/619 reads (5%) | catalogued as rs1172390535; called by muse, mutect2
- SIX3 | c.960C>T p.I320= | Silent (SNP) | VAF 30/516 reads (6%) | catalogued as COSV53228254; called by muse, mutect2
- SLC12A5 | c.1587C>T p.A529= (on ENST00000454036 / NM_001134771.2; = p.A506= on NM_020708.5) | Silent (SNP) | VAF 20/502 reads (4%) | catalogued as rs1322482267; called by muse, mutect2
- SLC2A4 | c.1233C>T p.F411= | Silent (SNP) | VAF 24/767 reads (3%) | called by muse, mutect2
- SLC38A4 | c.48G>A p.E16= | Silent (SNP) | VAF 22/391 reads (6%) | called by muse, mutect2
- SLC4A8 | c.2625C>T p.I875= | Silent (SNP) | VAF 32/596 reads (5%) | catalogued as COSV60652426; called by muse, mutect2
- SLC6A16 | c.189C>T p.T63= | Silent (SNP) | VAF 40/682 reads (6%) | called by muse, mutect2
- SLC6A5 | c.1305C>T p.I435= | Silent (SNP) | VAF 16/516 reads (3%) | called by muse, mutect2
- SLC6A9 | c.1707C>T p.P569= (on ENST00000360584 / NM_201649.4; = p.P515= on NM_006934.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 22/481 reads (5%) | catalogued as COSV62209973; called by muse, mutect2
- SLC7A14 | c.585C>T p.I195= | Silent (SNP) | VAF 37/467 reads (8%) | catalogued as rs201648790, COSV51592081; called by muse, mutect2
- SNCAIP | c.2220C>T p.S740= | Silent (SNP) | VAF 21/448 reads (5%) | catalogued as COSV54403623; called by muse, mutect2
- SOX13 | c.1699C>T p.L567= | Silent (SNP) | VAF 40/678 reads (6%) | called by muse, mutect2
- SPATA31A3 | c.2023C>T p.L675= | Silent (SNP) | VAF 12/432 reads (3%) | called by muse, mutect2
- SPATA31E1 | c.1107C>T p.I369= | Silent (SNP) | VAF 47/628 reads (7%) | catalogued as rs758158604, COSV100350009; called by muse, mutect2
- SPEF2 | c.2370C>T p.S790= | Silent (SNP) | VAF 17/382 reads (4%) | catalogued as COSV100607294; called by muse, mutect2
- SPEM2 | c.537G>A p.E179= | Silent (SNP) | VAF 20/578 reads (3%) | called by muse, mutect2
- SPHK2 | c.63G>A p.G21= | Silent (SNP) | VAF 22/539 reads (4%) | called by muse, mutect2
- SPNS1 | c.504C>T p.S168= | Silent (SNP) | VAF 29/627 reads (5%) | catalogued as rs1285586326; called by muse, mutect2
- SPNS3 | c.1488G>A p.L496= | Silent (SNP) | VAF 26/558 reads (5%) | called by muse, mutect2
- SSH3 | c.453C>T p.F151= | Silent (SNP) | VAF 17/380 reads (4%) | catalogued as rs1456978513; called by muse, mutect2
- STAB2 | c.3430C>T p.L1144= | Silent (SNP) | VAF 22/496 reads (4%) | called by muse, mutect2
- SURF6 | c.81G>A p.Q27= | Silent (SNP) | VAF 39/578 reads (7%) | called by muse, mutect2
- SV2A | c.1272C>T p.A424= | Silent (SNP) | VAF 28/560 reads (5%) | catalogued as rs938163544; called by muse, mutect2
- SYNJ1 | c.6G>A p.R2= | Silent (SNP) | VAF 27/453 reads (6%) | called by muse, mutect2
- SYT9 | c.678C>T p.F226= | Silent (SNP) | VAF 26/384 reads (7%) | catalogued as COSV59617802; called by muse, mutect2
- TARS2 | c.439C>T p.L147= | Silent (SNP) | VAF 31/502 reads (6%) | called by muse, mutect2
- TAS2R38 | c.372C>T p.F124= | Silent (SNP) | VAF 44/496 reads (9%) | catalogued as rs782592505, COSV71885828; called by muse, mutect2
- TBC1D4 | c.799C>T p.L267= | Silent (SNP) | VAF 38/802 reads (5%) | called by muse, mutect2
- TBC1D8 | c.799C>T p.L267= | Silent (SNP) | VAF 27/380 reads (7%) | called by muse, mutect2
- TBXA2R | c.993C>T p.S331= | Silent (SNP) | VAF 42/640 reads (7%) | called by muse, mutect2
- TEDC2 | c.1143C>T p.I381= | Silent (SNP) | VAF 48/750 reads (6%) | called by muse, mutect2
- TEDDM1 | c.198C>T p.P66= | Silent (SNP) | VAF 26/692 reads (4%) | called by muse, mutect2
- THAP12 | c.1269C>T p.C423= | Silent (SNP) | VAF 30/502 reads (6%) | called by muse, mutect2
- THSD7B | c.3882G>A p.Q1294= (on ENST00000272643; = p.Q1292= on NM_001316349.2) | Silent (SNP) | VAF 36/530 reads (7%) | called by muse, mutect2
- TIE1 | c.216C>T p.T72= | Silent (SNP) | VAF 29/855 reads (3%) | catalogued as rs1176363114; called by muse, mutect2
- TIGD3 | c.108G>A p.R36= | Silent (SNP) | VAF 24/489 reads (5%) | called by muse, mutect2
- TJP1 | c.297G>A p.G99= | Silent (SNP) | VAF 17/449 reads (4%) | called by muse, mutect2
- TMEM132B | c.780G>A p.G260= | Silent (SNP) | VAF 24/614 reads (4%) | catalogued as COSV54752632; called by muse, mutect2
- TMEM196 | c.144C>T p.S48= | Silent (SNP) | VAF 20/489 reads (4%) | catalogued as rs1266006765, COSV101337512; called by muse, mutect2
- TMEM255A | c.435C>T p.S145= | Silent (SNP) | VAF 28/474 reads (6%) | called by muse, mutect2
- TMEM30B | c.489C>T p.G163= | Silent (SNP) | VAF 27/624 reads (4%) | called by muse, mutect2
- TNXB | c.11631G>A p.G3877= (on ENST00000647633; = p.G3630= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 30/1008 reads (3%) | catalogued as rs536241123, COSV64477872; called by muse, mutect2
- TRIM6-TRIM34 | c.2148C>T p.I716= | Silent (SNP) | VAF 26/648 reads (4%) | called by muse, mutect2
- TRPM5 | c.2241C>T p.F747= | Silent (SNP) | VAF 41/690 reads (6%) | called by muse, mutect2
- TSPAN17 | c.105C>T p.F35= | Silent (SNP) | VAF 32/615 reads (5%) | called by muse, mutect2
- TTC12 | c.1471C>T p.L491= | Silent (SNP) | VAF 36/465 reads (8%) | called by muse, mutect2
- TTN | c.99465G>A p.E33155= (on ENST00000591111; = p.E25731= on NM_003319.4) | Silent (SNP) | VAF 22/457 reads (5%) | called by muse, mutect2
- TTN | c.8784G>A p.K2928= (on ENST00000591111; = p.K2882= on NM_003319.4) | Silent (SNP) | VAF 44/507 reads (9%) | catalogued as COSV60152966; called by muse, mutect2
- TUBGCP6 | c.441C>T p.G147= | Silent (SNP) | VAF 25/484 reads (5%) | called by muse, mutect2
- TYR | c.1434C>T p.L478= | Silent (SNP) | VAF 24/510 reads (5%) | catalogued as rs1314984978; called by muse, mutect2
- UBE2J2 | c.666C>T p.A222= | Silent (SNP) | VAF 30/816 reads (4%) | called by muse, mutect2
- UBN1 | c.2838C>T p.T946= | Silent (SNP) | VAF 32/622 reads (5%) | called by muse, mutect2
- UBN2 | c.3562C>T p.L1188= | Silent (SNP) | VAF 46/505 reads (9%) | catalogued as rs769222760, COSV99943991; called by muse, mutect2
- UNC5D | c.2604C>T p.P868= | Silent (SNP) | VAF 22/488 reads (5%) | catalogued as COSV99778559; called by muse, mutect2
63 further variants in this file (0 protein-altering or splice-affecting, 27 silent, 36 other) are not listed here.
